Somatic mutation profile of tumor specimen TCGA-EE-A3J7-06A (aliquot TCGA-EE-A3J7-06A-11D-A20D-08) from TCGA case TCGA-EE-A3J7, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 47.1 years (17,188 days).
Specimen TCGA-EE-A3J7-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3919e51a-a983-4f23-abe3-d48a123e5550.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EE-A3J7-10A (Blood Derived Normal), aliquot TCGA-EE-A3J7-10A-01D-A20D-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0ab29ec9-81b4-4594-98e5-7bdbc9ae8d9c

The open-access MAF lists 1,213 somatic variants for this specimen: 783 protein-altering or splice-affecting, 403 silent, 27 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 678, Silent 403, Nonsense Mutation 50, Splice Site 16, Splice Region 16, Frame Shift Del 15, Intron 12, RNA 10, Frame Shift Ins 3, 3'UTR 3, Translation Start Site 2, In Frame Del 2.

Variants (750 of 1,213; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTC1 | c.952G>A p.E318K | Missense Mutation (SNP) | VAF 191/212 reads (90%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.92); catalogued as rs730880403, COSV51757334; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CDKN2A | c.143C>T p.P48L | Missense Mutation (SNP) | VAF 121/152 reads (80%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as CM970251, COSV100446243, COSV58683273, COSV58688196; called by muse, mutect2, varscan2
- CREBBP | c.4336C>T p.R1446C | Missense Mutation (SNP) | VAF 16/68 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs398124146, COSV52113365, COSV52115600, COSV52116725; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- LAMB3 | c.124C>T p.R42* | Nonsense Mutation (SNP) | VAF 23/122 reads (19%) | catalogued as rs80356680, CM950743, COSV100620386; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MSH2 | c.1183C>T p.Q395* | Nonsense Mutation (SNP) | VAF 66/83 reads (80%) | catalogued as rs63750302, CM056004, COSV51883740; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 172/289 reads (60%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.722C>T p.S241F | Missense Mutation (SNP) | VAF 92/102 reads (90%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934573, CM1212186, CM920673, COSV52661688, COSV52662386, COSV52713934, COSV52760886; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA1 | c.4348C>T p.Q1450* | Nonsense Mutation (SNP) | VAF 17/42 reads (40%) | catalogued as COSV101037126; called by muse, mutect2, varscan2
- ABCA12 | c.1733G>A p.R578K (on ENST00000272895 / NM_173076.3; = p.R260K on NM_015657.3) | Missense Mutation (SNP) | VAF 41/53 reads (77%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as rs775306915, COSV55975019; called by muse, mutect2, varscan2
- ABI3BP | c.2138C>T p.P713L | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as COSV52551073; called by muse, mutect2, varscan2
- ABLIM1 | c.2260G>A p.G754R | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.914); catalogued as COSV53315703; called by muse, mutect2, varscan2
- AC068580.4 | c.911C>T p.P304L | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs780328613, COSV99362418; called by muse, mutect2, varscan2
- AC068580.4 | c.910C>T p.P304S | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as COSV52589162, COSV99362420; called by muse, varscan2
- ACMSD | c.849+1G>A p.X283_splice | Splice Site (SNP) | VAF 41/55 reads (75%) | catalogued as COSV51609660; called by muse, mutect2, varscan2
- ACOT12 | c.1642G>T p.D548Y | Missense Mutation (SNP) | VAF 71/76 reads (93%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.316); catalogued as rs771572593, COSV56898062; called by muse, mutect2, varscan2
- ACSM1 | c.1168G>A p.G390R | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs866290559, COSV99533066; called by muse, mutect2, varscan2
- ACTA2 | c.941G>A p.R314Q | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as rs1415888089, COSV56518104; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACTG2 | c.599C>T p.S200F | Missense Mutation (SNP) | VAF 74/97 reads (76%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.878); catalogued as COSV61829653; called by muse, mutect2, varscan2
- ACTN3 | c.2390G>A p.G797E | Missense Mutation (SNP) | VAF 107/321 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as COSV59750456; called by muse, mutect2, varscan2
- ADAM7 | c.1052C>T p.T351I | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.966); catalogued as rs368102767; called by muse, mutect2, varscan2
- ADAM8 | c.185G>A p.G62E | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.106); catalogued as COSV69865327; called by muse, mutect2, varscan2
- ADAMDEC1 | c.784C>T p.Q262* | Nonsense Mutation (SNP) | VAF 38/103 reads (37%) | catalogued as COSV56477562, COSV99835943; called by muse, mutect2, varscan2
- ADAMTS18 | c.2555C>T p.P852L | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.159); catalogued as rs768952316, COSV51422961; called by muse, mutect2, varscan2
- ADAMTS2 | c.3581G>A p.R1194K | Missense Mutation (SNP) | VAF 86/103 reads (83%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.97); catalogued as COSV52367710, COSV52392772; called by muse, mutect2, varscan2
- ADAMTS8 | c.1006G>A p.D336N | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.02); catalogued as COSV57297612; called by muse, mutect2, varscan2
- ADGRE5 | c.586C>T p.P196S | Missense Mutation (SNP) | VAF 66/225 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.044); catalogued as COSV54414709; called by muse, varscan2
- AGO3 | c.1942C>T p.R648W | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV55796264, COSV55797040; called by muse, mutect2, varscan2
- AHDC1 | c.3185C>A p.T1062K | Missense Mutation (SNP) | VAF 6/8 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV55942319; called by muse, mutect2
- AHNAK2 | c.7810G>A p.A2604T | Missense Mutation (SNP) | VAF 184/210 reads (88%) | SIFT tolerated (0.36); PolyPhen benign (0.06); catalogued as COSV60930139; called by muse, varscan2
- AIM2 | c.961G>A p.G321R | Missense Mutation (SNP) | VAF 17/197 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.019); catalogued as COSV63702010; called by muse, mutect2
- AKR1C4 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 45/114 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.033); catalogued as COSV54125527; called by muse, mutect2, varscan2
- AKR1D1 | c.142G>A p.G48R | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs773852919, COSV54337110, COSV99653217; called by muse, mutect2, varscan2
- AL592490.1 | c.628C>T p.P210S | Missense Mutation (SNP) | VAF 99/186 reads (53%) | SIFT tolerated (0.12); PolyPhen benign (0.091); catalogued as COSV69427833; called by muse, mutect2, varscan2
- ALDH7A1 | c.1211G>A p.R404H | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.034); catalogued as rs771975420, COSV63160888; called by muse, mutect2, varscan2
- ALPK2 | c.1568del p.K523Rfs*15 | Frame Shift Del (DEL) | VAF 69/372 reads (19%) | catalogued as rs1341338515; called by pindel, varscan2
- AMBP | c.928G>A p.G310R | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54325559; called by muse, mutect2, varscan2
- AMBP | c.685G>A p.D229N | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV54325566; called by muse, mutect2, varscan2
- AMHR2 | c.89C>T p.P30L | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.033); catalogued as rs576863737, COSV57686937; called by muse, mutect2, varscan2
- AMZ1 | c.1261G>A p.E421K | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.054); catalogued as rs781447320, COSV56689045; called by muse, mutect2, varscan2
- ANK1 | c.3469G>A p.D1157N | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs747027965, COSV55895567; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANKMY2 | c.940T>G p.F314V | Missense Mutation (SNP) | VAF 41/141 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.313); catalogued as COSV61012723; called by muse, mutect2, varscan2
- ANKRD13A | c.349C>A p.L117I | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.196); catalogued as COSV55675419, COSV55678311; called by muse, mutect2, varscan2
- ANKRD30A | c.2806G>A p.D936N (on ENST00000611781; = p.D880N on NM_052997.2) | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.019); catalogued as rs749042816, COSV64620079, COSV64620914, COSV64624217; called by muse, mutect2, varscan2
- ANKRD30A | c.2960G>A p.G987E (on ENST00000611781; = p.G931E on NM_052997.2) | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.7); PolyPhen benign (0.019); catalogued as COSV64620926, COSV64623054; called by muse, mutect2
- ANLN | c.2393T>C p.M798T | Missense Mutation (SNP) | VAF 61/154 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV56078918; called by muse, mutect2, varscan2
- ANO1 | c.986G>A p.G329D | Missense Mutation (SNP) | VAF 55/195 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV60283765; called by muse, mutect2, varscan2
- ANO2 | c.1572G>A p.W524* (on ENST00000356134 / NM_001278597.3; = p.W528* on NM_001278596.3) | Nonsense Mutation (SNP) | VAF 4/11 reads (36%) | catalogued as rs1388942950, COSV59042908; called by mutect2, varscan2
- AOC1 | c.1265C>T p.P422L | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV62870803; called by muse, mutect2, varscan2
- AP1B1 | c.1684G>A p.E562K | Missense Mutation (SNP) | VAF 22/195 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.481); catalogued as COSV58023385; called by muse, mutect2, varscan2
- AP2A2 | c.926T>G p.L309R | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59963941; called by muse, mutect2, varscan2
- APBB1 | c.1550C>T p.S517F | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.674); catalogued as COSV54980118, COSV54980444; called by muse, mutect2, varscan2
- APC2 | c.1682C>T p.S561F | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52022041; called by muse, mutect2, varscan2
- APOC1 | c.195G>T p.R65= | Splice Region (SNP) | VAF 191/397 reads (48%) | catalogued as COSV52992321; called by muse, mutect2, varscan2
- ARAP2 | c.203T>G p.L68W | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV58291626, COSV58291997; called by muse, mutect2, varscan2
- ARFGAP3 | c.680C>T p.A227V | Missense Mutation (SNP) | VAF 65/149 reads (44%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.824); catalogued as rs1205603368, COSV99605341; called by muse, mutect2, varscan2
- ARHGAP15 | c.262A>C p.K88Q | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.985); catalogued as COSV54520581; called by muse, mutect2, varscan2
- ARHGAP29 | c.2330A>G p.Q777R | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT tolerated (0.53); PolyPhen benign (0.115); catalogued as rs946146631, COSV53116896; called by muse, mutect2, varscan2
- ARHGAP29 | c.10C>T p.H4Y | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); catalogued as COSV53116910; called by muse, mutect2, varscan2
- ARHGAP45 | c.1786G>A p.E596K | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.026); catalogued as COSV57436327; called by muse, mutect2, varscan2
- ARHGEF2 | c.2860C>T p.R954C (on ENST00000361247 / NM_001162383.2; = p.R926C on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 57/221 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.799); catalogued as rs1197073648, COSV58109630; called by muse, mutect2, varscan2
- ARID4B | c.2912C>T p.T971I | Missense Mutation (SNP) | VAF 159/173 reads (92%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.986); catalogued as COSV51611096; called by muse, mutect2, varscan2
- ARL14 | c.383C>T p.P128L | Missense Mutation (SNP) | VAF 46/104 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.469); catalogued as COSV57900461; called by muse, mutect2, varscan2
- ARMC12 | c.113G>A p.G38D | Missense Mutation (SNP) | VAF 36/69 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1271733924, COSV55361683; called by muse, varscan2
- ARRB1 | c.973G>A p.V325M | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV63575897, COSV63577484; called by muse, mutect2, varscan2
- ARSG | c.1507T>C p.Y503H | Missense Mutation (SNP) | VAF 159/356 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV50931703; called by muse, mutect2, varscan2
- ART1 | c.587G>A p.R196K | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99167186; called by muse, mutect2, varscan2
- ASB5 | c.337G>A p.G113R | Missense Mutation (SNP) | VAF 94/148 reads (64%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.9); catalogued as COSV56674340; called by muse, mutect2, varscan2
- ATE1 | c.479A>G p.K160R | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV56443148; called by muse, mutect2, varscan2
- ATF4 | c.680C>T p.S227F | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as rs757102478, COSV57480664; called by muse, mutect2, varscan2
- ATF7IP | c.902C>T p.P301L | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.007); catalogued as COSV53777526; called by muse, mutect2, varscan2
- ATG2A | c.2327C>T p.P776L | Missense Mutation (SNP) | VAF 11/16 reads (69%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV65968860; called by muse, varscan2
- ATP1A4 | c.2581G>A p.G861R | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.999); catalogued as COSV63628498; called by muse, mutect2, varscan2
- ATP2B4 | c.2200G>A p.E734K | Missense Mutation (SNP) | VAF 81/86 reads (94%) | SIFT tolerated (0.2); PolyPhen benign (0.23); catalogued as rs767252454, COSV58181887; called by muse, mutect2, varscan2
- ATP7B | c.2509G>A p.G837R | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as CM136594, COSV54443976; called by muse, mutect2, varscan2
- ATPAF1 | c.766A>G p.T256A (on ENST00000574428; = p.T279A on NM_022745.4) | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.857); catalogued as rs376154299; called by muse, mutect2, varscan2
- BAHCC1 | c.4442G>A p.R1481Q | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1403595323, COSV57033101; called by muse, mutect2, varscan2
- BAZ2A | c.5284C>T p.R1762W | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs945630741, COSV99466554, COSV99467211; called by muse, mutect2, varscan2
- BLVRA | c.475G>T p.E159* | Nonsense Mutation (SNP) | VAF 155/535 reads (29%) | catalogued as COSV55516293, COSV99039333; called by muse, mutect2, varscan2
- BMP3 | c.820G>A p.D274N | Missense Mutation (SNP) | VAF 31/52 reads (60%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs776862828, COSV51095050; called by muse, mutect2, varscan2
- BMP5 | c.967A>C p.N323H | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV100896020; called by muse, mutect2, varscan2
- BMP5 | c.966A>T p.K322N | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV100896021; called by muse, mutect2, varscan2
- BOLA1 | c.342G>A p.W114* | Nonsense Mutation (SNP) | VAF 26/85 reads (31%) | catalogued as COSV64967595; called by muse, mutect2, varscan2
- BPIFB1 | c.1090G>A p.E364K | Missense Mutation (SNP) | VAF 60/241 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as COSV53608800; called by muse, mutect2, varscan2
- BRCA2 | c.10194G>T p.Q3398H | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV58414012; called by muse, mutect2, varscan2
- BRINP1 | c.624C>A p.D208E | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.112); catalogued as COSV56312918; called by muse, mutect2
- C16orf71 | c.1478C>T p.P493L | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as rs1475889370, COSV54789947; called by muse, mutect2, varscan2
- C1R | c.199G>A p.G67R (on ENST00000536053 / NM_001354346.2; = p.G53R on NM_001733.7) | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99864751; called by muse, mutect2, varscan2
- C1orf105 | c.400C>T p.P134S | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT tolerated (0.64); PolyPhen benign (0.007); catalogued as COSV62959411; called by muse, mutect2, varscan2
- C1orf127 | c.2368C>T p.Q790* | Nonsense Mutation (SNP) | VAF 9/31 reads (29%) | catalogued as rs1275461264, COSV100983491; called by muse, mutect2, varscan2
- C2orf78 | c.1112A>C p.K371T | Missense Mutation (SNP) | VAF 32/41 reads (78%) | SIFT tolerated (0.18); PolyPhen benign (0.202); catalogued as COSV68519378; called by muse, mutect2, varscan2
- C3 | c.4720G>A p.D1574N | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99836793; called by muse, mutect2, varscan2
- C3 | c.1103T>G p.M368R | Missense Mutation (SNP) | VAF 94/264 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as COSV55581258; called by muse, mutect2, varscan2
- C3AR1 | c.233C>T p.S78L | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.841); catalogued as rs376269642, COSV50821158; called by muse, mutect2, varscan2
- CACNA1I | c.3981C>T p.L1327= | Splice Region (SNP) | VAF 174/437 reads (40%) | catalogued as COSV60805297, COSV60818417; called by muse, mutect2, varscan2
- CACNA1S | c.5389C>A p.L1797M | Missense Mutation (SNP) | VAF 34/116 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV62943541; called by muse, mutect2, varscan2
- CACNA2D4 | c.2386G>A p.D796N | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV54959836; called by muse, mutect2, varscan2
- CACNB2 | c.1657G>A p.E553K (on ENST00000324631 / NM_201596.3; = p.E498K on NM_000724.4) | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.524); catalogued as COSV56624879; called by muse, mutect2, varscan2
- CACNG3 | c.763C>T p.H255Y | Missense Mutation (SNP) | VAF 68/134 reads (51%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV50083100; called by muse, mutect2, varscan2
- CAMK2B | c.769C>T p.P257S | Missense Mutation (SNP) | VAF 84/182 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV51666414; called by muse, varscan2
- CASR | c.1625T>C p.F542S (on ENST00000490131; = p.F619S on NM_000388.4) | Missense Mutation (SNP) | VAF 48/108 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.09); catalogued as COSV56133793; called by muse, mutect2, varscan2
- CBLC | c.128C>T p.S43L | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.989); catalogued as COSV54325811; called by muse, mutect2, varscan2
- CCDC149 | c.247C>T p.P83S | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.426); catalogued as rs746592878, COSV60882067; called by muse, mutect2, varscan2
- CCDC191 | c.2744G>A p.R915K | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as rs1411163741, COSV55676221; called by muse, mutect2, varscan2
- CCDC38 | c.352G>A p.D118N | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.037); catalogued as COSV60184969; called by muse, mutect2, varscan2
- CCDC86 | c.247G>A p.G83R | Missense Mutation (SNP) | VAF 39/73 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV57126321; called by muse, mutect2, varscan2
- CCL22 | c.232G>A p.D78N | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.61); catalogued as rs368622742; called by muse, mutect2, varscan2
- CCP110 | c.2471G>A p.R824Q | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.117); catalogued as rs772276382, COSV66818154; called by muse, mutect2, varscan2
- CCR8 | c.112C>T p.L38F | Missense Mutation (SNP) | VAF 81/89 reads (91%) | SIFT tolerated (0.14); PolyPhen benign (0.18); catalogued as COSV58337969; called by muse, mutect2, varscan2
- CCT8L2 | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 53/130 reads (41%) | SIFT tolerated (0.58); PolyPhen benign (0.011); catalogued as COSV63463437; called by muse, mutect2, varscan2
- CD163 | c.1103G>A p.G368E | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0.076); catalogued as COSV63137046; called by muse, mutect2, varscan2
- CD163 | c.553G>A p.D185N | Missense Mutation (SNP) | VAF 67/229 reads (29%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.965); catalogued as COSV63137055; called by muse, mutect2, varscan2
- CD226 | c.278T>C p.L93P | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54616086; called by muse, mutect2, varscan2
- CDH8 | c.1843C>T p.L615F | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.033); catalogued as COSV54899253; called by muse, mutect2, varscan2
- CDH8 | c.1433C>T p.S478L | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV54899223, COSV54903049; called by muse, mutect2, varscan2
- CDS1 | c.789del p.F263Lfs*6 | Frame Shift Del (DEL) | VAF 19/88 reads (22%) | catalogued as rs759091263; called by mutect2, varscan2
- CEACAM4 | c.41C>T p.P14L | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.807); catalogued as COSV55733085; called by muse, mutect2, varscan2
- CELF4 | c.658G>A p.G220R | Missense Mutation (SNP) | VAF 58/170 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV58465934; called by muse, mutect2, varscan2
- CELSR3 | c.1855C>T p.R619C | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs776080561, COSV51148698; called by muse, mutect2, varscan2
- CENPJ | c.1015G>A p.E339K | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67884232; called by muse, mutect2, varscan2
- CEP350 | c.4886C>T p.P1629L | Missense Mutation (SNP) | VAF 33/37 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62609594; called by muse, mutect2, varscan2
- CFAP43 | c.1852C>T p.P618S | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.39); PolyPhen benign (0.119); catalogued as COSV53381173; called by muse, mutect2, varscan2
- CFAP46 | c.6853C>T p.L2285F | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV54159399; called by muse, mutect2, varscan2
- CFAP57 | c.1887G>C p.K629N | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV65265752; called by muse, mutect2, varscan2
- CFAP65 | c.4033G>A p.E1345K | Missense Mutation (SNP) | VAF 27/36 reads (75%) | SIFT tolerated (0.14); PolyPhen benign (0.024); catalogued as COSV58566143; called by muse, mutect2, varscan2
- CFHR1 | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 61/199 reads (31%) | SIFT tolerated (0.93); PolyPhen benign (0.011); catalogued as COSV57628545; called by muse, mutect2, varscan2
- CFTR | c.709C>T p.Q237* | Nonsense Mutation (SNP) | VAF 30/58 reads (52%) | catalogued as CM941971, COSV50041069; called by muse, mutect2, varscan2
- CGN | c.328G>A p.G110R | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT tolerated (0.65); PolyPhen benign (0.012); catalogued as rs1241659845, COSV54973618; called by muse, mutect2, varscan2
- CHGB | c.781G>A p.E261K | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as COSV66761730; called by muse, mutect2, varscan2
- CHRNA2 | c.395C>T p.S132F | Missense Mutation (SNP) | VAF 53/156 reads (34%) | SIFT tolerated (0.85); PolyPhen probably damaging (0.932); catalogued as COSV53559706; called by muse, mutect2
- CIC | c.1724C>T p.P575L | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as COSV99359739; called by muse, mutect2, varscan2
- CIITA | c.1633C>A p.L545I | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.2); catalogued as COSV60862017; called by muse, mutect2, varscan2
- CIT | c.4474G>A p.E1492K | Missense Mutation (SNP) | VAF 43/87 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.197); catalogued as COSV55882839; called by muse, mutect2, varscan2
- CLCA4 | c.1807G>A p.D603N | Missense Mutation (SNP) | VAF 36/70 reads (51%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.461); catalogued as COSV55371121; called by muse, mutect2, varscan2
- CLEC14A | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 61/68 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60562180; called by muse, mutect2, varscan2
- CLEC4D | c.384+1G>A p.X128_splice | Splice Site (SNP) | VAF 16/53 reads (30%) | catalogued as rs777592191, COSV55230839; called by muse, mutect2, varscan2
- CLEC4M | c.829G>A p.G277R | Missense Mutation (SNP) | VAF 36/107 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.398); catalogued as COSV50224256; called by muse, mutect2, varscan2
- CLK2 | c.260G>T p.G87V | Missense Mutation (SNP) | VAF 253/501 reads (50%) | SIFT tolerated (0.19); PolyPhen benign (0.076); catalogued as COSV62878207; called by muse, mutect2, varscan2
- CLSTN3 | c.1453G>A p.E485K | Missense Mutation (SNP) | VAF 126/248 reads (51%) | SIFT tolerated (0.05); PolyPhen benign (0.439); catalogued as COSV56940267; called by muse, mutect2, varscan2
- CLTCL1 | c.3877C>T p.R1293C | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as rs781805918, COSV54238893; called by muse, mutect2, varscan2
- CMYA5 | c.8980G>A p.D2994N | Missense Mutation (SNP) | VAF 14/14 reads (100%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV71409413; called by muse, mutect2, varscan2
- CNKSR2 | c.1108C>T p.L370F | Missense Mutation (SNP) | VAF 12/15 reads (80%) | SIFT tolerated (0.49); PolyPhen benign (0.033); catalogued as COSV54266057; called by muse, mutect2, varscan2
- CNOT1 | c.2557C>T p.Q853* | Nonsense Mutation (SNP) | VAF 20/105 reads (19%) | catalogued as COSV55322223; called by muse, mutect2, varscan2
- CNTNAP3 | c.1850C>T p.P617L | Missense Mutation (SNP) | VAF 38/50 reads (76%) | SIFT deleterious (0); PolyPhen benign (0.399); catalogued as COSV52675478; called by muse, mutect2, varscan2
- COBL | c.596G>A p.R199K | Missense Mutation (SNP) | VAF 35/63 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV54358168; called by muse, mutect2, varscan2
- COG3 | c.2000T>C p.L667S | Missense Mutation (SNP) | VAF 66/99 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as COSV63075229; called by muse, mutect2, varscan2
- COL11A1 | c.3494G>A p.G1165E | Missense Mutation (SNP) | VAF 42/74 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62177548; called by muse, mutect2, varscan2
- COL28A1 | c.1483G>A p.V495M | Missense Mutation (SNP) | VAF 74/130 reads (57%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as COSV68084599; called by muse, mutect2, varscan2
- COL4A4 | c.3479G>A p.G1160E | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61636474; called by muse, mutect2
- COL4A4 | c.1522C>T p.P508S | Missense Mutation (SNP) | VAF 36/50 reads (72%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.575); catalogued as COSV61629409; called by muse, mutect2, varscan2
- COL5A1 | c.2487G>A p.G829= | Splice Region (SNP) | VAF 8/50 reads (16%) | catalogued as COSV65670485, COSV65674552; called by muse, mutect2, varscan2
- COL5A1 | c.5373C>T p.T1791= | Splice Region (SNP) | VAF 23/75 reads (31%) | catalogued as COSV65674555; called by muse, mutect2, varscan2
- COL5A3 | c.988A>T p.T330S | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV53418914; called by muse, mutect2, varscan2
- COL6A3 | c.1007G>A p.R336Q | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as rs745667305, COSV99798957; ClinVar: uncertain significance; called by muse, varscan2
- COQ5 | c.866G>A p.R289Q | Missense Mutation (SNP) | VAF 23/190 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); catalogued as rs775225793, COSV56020420; called by muse, mutect2, varscan2
- CORIN | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 32/135 reads (24%) | SIFT tolerated (0.48); PolyPhen benign (0.205); catalogued as rs866164544, COSV56688788; called by muse, mutect2, varscan2
- COX4I2 | c.208G>A p.G70R | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65781852; called by muse, mutect2, varscan2
- CPEB4 | c.1736G>A p.R579Q | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV54171171; called by muse, mutect2, varscan2
- CPED1 | c.2843G>A p.G948E | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59997999; called by muse, mutect2, varscan2
- CRB1 | c.2465G>A p.W822* | Nonsense Mutation (SNP) | VAF 19/24 reads (79%) | catalogued as HM0693, COSV66333528; called by muse, mutect2, varscan2
- CROCC | c.3148G>A p.D1050N | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.333); catalogued as rs751961465, COSV65014820; called by muse, mutect2, varscan2
- CSDE1 | c.1834C>T p.Q612* (on ENST00000358528 / NM_001007553.3; = p.Q581* on NM_007158.6) | Nonsense Mutation (SNP) | VAF 216/415 reads (52%) | catalogued as COSV54759343; called by muse, mutect2, varscan2
- CSF3 | c.391G>A p.E131K | Missense Mutation (SNP) | VAF 147/178 reads (83%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.574); catalogued as rs368443474; called by muse, mutect2, varscan2
- CSMD1 | c.8718G>A p.W2906* (on ENST00000520002; = p.W2905* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 37/92 reads (40%) | catalogued as COSV59381557; called by muse, mutect2, varscan2
- CTNNA3 | c.503C>T p.S168F | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.567); catalogued as COSV57722073; called by muse, mutect2, varscan2
- CTTN | c.814A>G p.K272E | Missense Mutation (SNP) | VAF 168/539 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.111); catalogued as COSV57236127; called by muse, mutect2, varscan2
- CUX2 | c.1225C>T p.L409F | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.823); catalogued as COSV55627371; called by muse, mutect2, varscan2
- CXorf58 | c.637C>T p.P213S | Missense Mutation (SNP) | VAF 41/48 reads (85%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV64858836; called by muse, mutect2, varscan2
- CYP24A1 | c.1541G>A p.R514Q | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs986387333, COSV53776642; called by muse, mutect2, varscan2
- CYP26A1 | c.1408G>A p.G470R | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT tolerated (0.71); PolyPhen benign (0.115); catalogued as COSV56419946; called by muse, mutect2, varscan2
- CYP2C8 | c.232C>T p.H78Y | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT tolerated (0.24); PolyPhen benign (0.04); catalogued as rs866172214, COSV64878905; called by muse, mutect2, varscan2
- CYP2C9 | c.454C>T p.L152F | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV53250111; called by muse, mutect2, varscan2
- CYP3A43 | c.458G>A p.G153E | Missense Mutation (SNP) | VAF 39/65 reads (60%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as COSV55937981, COSV99732955; called by muse, mutect2, varscan2
- DCAF8L1 | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 81/92 reads (88%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as rs767977769, COSV71595101; called by muse, mutect2, varscan2
- DCDC1 | c.2024G>A p.G675E | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs762260714, COSV60834981; called by muse, mutect2, varscan2
- DCUN1D1 | c.158G>A p.R53Q | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0.048); catalogued as rs1298281414, COSV53046079; called by muse, mutect2
- DDI2 | c.590C>T p.P197L | Missense Mutation (SNP) | VAF 267/454 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as COSV60781452; called by muse, mutect2, varscan2
- DDX27 | c.1934T>C p.V645A | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV65610713; called by muse, mutect2, varscan2
- DDX3X | c.850G>A p.E284K (on ENST00000399959; = p.E285K on NM_001356.5) | Missense Mutation (SNP) | VAF 12/13 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67864532; called by muse, mutect2, varscan2
- DENND4B | c.1046C>T p.P349L | Missense Mutation (SNP) | VAF 45/129 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63411866; called by muse, mutect2, varscan2
- DERL2 | c.356T>C p.F119S | Missense Mutation (SNP) | VAF 78/86 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV50147938; called by muse, mutect2, varscan2
- DGCR8 | c.467G>A p.S156N | Missense Mutation (SNP) | VAF 200/432 reads (46%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV61228652; called by muse, mutect2, varscan2
- DGKQ | c.2632C>T p.R878* | Nonsense Mutation (SNP) | VAF 27/54 reads (50%) | catalogued as rs775584332, COSV53278559; called by muse, mutect2, varscan2
- DIO1 | c.175G>A p.D59N | Missense Mutation (SNP) | VAF 128/280 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.554); catalogued as COSV50779698; called by muse, mutect2, varscan2
- DIP2A | c.3646C>T p.Q1216* | Nonsense Mutation (SNP) | VAF 32/121 reads (26%) | catalogued as COSV59486743; called by muse, mutect2, varscan2
- DISP2 | c.811G>A p.D271N | Missense Mutation (SNP) | VAF 44/47 reads (94%) | SIFT tolerated (0.39); PolyPhen benign (0.037); catalogued as COSV51142257; called by muse, mutect2, varscan2
- DLX3 | c.266G>A p.G89E | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.405); catalogued as COSV71547934; called by muse, mutect2
- DMC1 | c.385C>T p.R129C | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201014421, COSV53258054; called by muse, mutect2, varscan2
- DNAH11 | c.2146C>T p.L716F | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV60980729; called by muse, mutect2, varscan2
- DNAH17 | c.11529G>A p.K3843= | Splice Region (SNP) | VAF 27/51 reads (53%) | catalogued as COSV67760972; called by muse, mutect2, varscan2
- DNAH17 | c.4204G>A p.D1402N | Missense Mutation (SNP) | VAF 91/302 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV101102577; called by muse, mutect2, varscan2
- DNAH2 | c.2191C>T p.R731C | Missense Mutation (SNP) | VAF 37/48 reads (77%) | SIFT tolerated (0.09); PolyPhen benign (0.082); catalogued as rs772733027, COSV66717732; called by muse, mutect2, varscan2
- DNAH5 | c.10202G>A p.G3401E | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV54251201; called by muse, mutect2, varscan2
- DNAH5 | c.9287G>A p.R3096Q | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as rs1388732051, COSV54203252; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH7 | c.9997C>T p.R3333* | Nonsense Mutation (SNP) | VAF 67/87 reads (77%) | catalogued as COSV56760021; called by muse, mutect2, varscan2
- DNAH8 | c.13387T>G p.F4463V | Missense Mutation (SNP) | VAF 51/148 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.41); catalogued as COSV59479597; called by muse, mutect2, varscan2
- DNAH9 | c.2595G>A p.Q865= | Splice Region (SNP) | VAF 70/72 reads (97%) | catalogued as rs781231969, COSV52376254, COSV52381736; called by muse, mutect2, varscan2
- DNER | c.1866G>A p.W622* | Nonsense Mutation (SNP) | VAF 39/53 reads (74%) | catalogued as rs866256730, COSV59163145; called by muse, mutect2, varscan2
- DNM2 | c.2434C>T p.R812W (on ENST00000355667 / NM_001005360.3; = p.R808W on NM_004945.3) | Missense Mutation (SNP) | VAF 89/264 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as COSV53035374; called by muse, mutect2, varscan2
- DOCK11 | c.4692G>A p.M1564I | Missense Mutation (SNP) | VAF 19/19 reads (100%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV52247466; called by muse, mutect2
- DOCK2 | c.2032-1G>A p.X678_splice | Splice Site (SNP) | VAF 54/66 reads (82%) | catalogued as COSV56987332; called by muse, mutect2, varscan2
- DOCK9 | c.433G>A p.D145N (on ENST00000376460 / NM_001366676.2; = p.D146N on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 58/171 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.12); catalogued as COSV59643103; called by muse, mutect2, varscan2
- DSC2 | c.1143G>T p.K381N | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.596); catalogued as COSV51869246, COSV99199576; called by muse, mutect2, varscan2
- DSG4 | c.2500G>A p.E834K | Missense Mutation (SNP) | VAF 50/101 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.3); catalogued as COSV57397591; called by muse, mutect2, varscan2
- DTD1 | c.440C>T p.S147L | Missense Mutation (SNP) | VAF 44/106 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs780336372, COSV66282143; called by muse, varscan2
- DUSP22 | c.337G>A p.D113N | Missense Mutation (SNP) | VAF 109/451 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.244); catalogued as rs1421419698, COSV100739808; called by muse, mutect2, varscan2
- DUSP29 | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 47/123 reads (38%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as rs879440427, COSV58301582; called by muse, mutect2, varscan2
- DYNC2H1 | c.12686G>A p.G4229E | Missense Mutation (SNP) | VAF 24/26 reads (92%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV62106504; called by muse, mutect2, varscan2
- E2F7 | c.1508C>T p.S503F | Missense Mutation (SNP) | VAF 65/140 reads (46%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.65); catalogued as COSV59740741, COSV59742907; called by muse, mutect2, varscan2
- ECRG4 | c.326G>A p.R109Q | Missense Mutation (SNP) | VAF 13/152 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs769838546, COSV53000263; called by muse, mutect2
- EFCAB7 | c.1505C>T p.P502L | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV64315360; called by muse, mutect2, varscan2
- EGFLAM | c.1641G>A p.M547I | Missense Mutation (SNP) | VAF 35/49 reads (71%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV59316963; called by muse, mutect2, varscan2
- ELMO1 | c.701G>A p.G234E | Missense Mutation (SNP) | VAF 52/200 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV60324258; called by muse, mutect2, varscan2
- ENOPH1 | c.475G>A p.A159T | Missense Mutation (SNP) | VAF 164/266 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56732217; called by muse, mutect2, varscan2
- ENPP3 | c.796G>A p.A266T | Missense Mutation (SNP) | VAF 47/52 reads (90%) | SIFT tolerated (0.12); PolyPhen benign (0.07); catalogued as COSV62956641; called by muse, mutect2, varscan2
- ENTPD3 | c.1543A>C p.K515Q | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV57196322; called by muse, mutect2, varscan2
- ENTPD8 | c.704C>T p.S235F | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV58163719; called by muse, mutect2, varscan2
- EPHA2 | c.985C>T p.P329S | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64454692; called by muse, mutect2
- EPHA8 | c.1807A>G p.K603E | Missense Mutation (SNP) | VAF 49/146 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.078); catalogued as COSV51298237; called by muse, mutect2, varscan2
- EPHB1 | c.440C>T p.S147F | Missense Mutation (SNP) | VAF 86/215 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67669953; called by muse, mutect2, varscan2
- EPHB6 | c.165+1dup | Frame Shift Ins (INS) | VAF 22/172 reads (13%) | catalogued as rs771807343; called by mutect2, varscan2
- EPS15L1 | c.2066C>T p.S689L | Missense Mutation (SNP) | VAF 47/103 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.226); catalogued as rs374304767, COSV50175115, COSV99933558; called by muse, mutect2, varscan2
- EPYC | c.194G>A p.G65E | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV53799935; called by muse, mutect2, varscan2
- ERCC6L | c.1185G>A p.M395I | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.066); catalogued as COSV57822354; called by muse, mutect2, varscan2
- ERICH3 | c.941A>T p.Y314F | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.799); catalogued as COSV58618110; called by muse, mutect2, varscan2
- ERICH6 | c.493C>T p.P165S | Missense Mutation (SNP) | VAF 107/246 reads (43%) | SIFT tolerated (0.55); PolyPhen benign (0.025); catalogued as COSV55802755; called by muse, mutect2, varscan2
- EXOC3L4 | c.1933C>T p.Q645* | Nonsense Mutation (SNP) | VAF 129/314 reads (41%) | catalogued as COSV101197632; called by muse, mutect2, varscan2
- F10 | c.634G>A p.E212K | Missense Mutation (SNP) | VAF 37/140 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs556947824, COSV65023131; called by muse, mutect2, varscan2
- F9 | c.1108C>T p.Q370* | Nonsense Mutation (SNP) | VAF 42/47 reads (89%) | catalogued as CM940652, CM960599, COSV54382355; called by muse, mutect2, varscan2
- F9 | c.1228G>A p.D410N | Missense Mutation (SNP) | VAF 58/61 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as CM005427, CM940694, CM940695, COSV54382360; called by muse, mutect2, varscan2
- FAAP100 | c.842C>T p.P281L | Missense Mutation (SNP) | VAF 53/57 reads (93%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV59887566; called by muse, mutect2, varscan2
- FADS3 | c.1033C>T p.P345S | Missense Mutation (SNP) | VAF 29/142 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); catalogued as COSV53880513; called by muse, mutect2, varscan2
- FAM131B | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 54/93 reads (58%) | SIFT tolerated (0.22); PolyPhen benign (0.439); catalogued as rs757283523, COSV58374346; called by muse, mutect2, varscan2
- FAM155A | c.1096G>A p.E366K | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV65562127; called by muse, mutect2, varscan2
- FAM47C | c.165G>A p.M55I | Missense Mutation (SNP) | VAF 28/30 reads (93%) | SIFT deleterious (0.04); PolyPhen benign (0.341); catalogued as COSV100792978, COSV63730307; called by muse, mutect2, varscan2
- FAM53B | c.809C>T p.P270L | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as COSV55101302; called by muse, mutect2, varscan2
- FANCA | c.3557G>A p.R1186K | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.85); PolyPhen benign (0.005); catalogued as COSV57071490, COSV57073134; called by muse, mutect2, varscan2
- FAR1 | c.1078C>T p.P360S | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100701591; called by muse, mutect2, varscan2
- FBXL13 | c.2194G>A p.D732N | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.011); catalogued as COSV57544330; called by muse, mutect2, varscan2
- FBXW10 | c.1402C>T p.L468F | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57322191; called by mutect2, varscan2
- FCRL1 | c.1218G>A p.K406= | Splice Region (SNP) | VAF 45/92 reads (49%) | catalogued as rs1306297159, COSV63827408; called by muse, mutect2, varscan2
- FCRL5 | c.1693C>T p.R565C | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs758024949, COSV62512930; called by muse, mutect2, varscan2
- FCRL5 | c.82C>A p.Q28K | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV100709010, COSV62520047; called by muse, mutect2, varscan2
- FER1L5 | c.4043G>A p.G1348D (on ENST00000623019; = p.G1321D on NM_001293083.2) | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753014548, COSV67607027; called by muse, mutect2, varscan2
- FGA | c.968C>T p.P323L | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.366); catalogued as COSV57400704; called by muse, mutect2, varscan2
- FGF13 | c.727G>A p.E243K | Missense Mutation (SNP) | VAF 89/102 reads (87%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as COSV59544213, COSV59550200; called by muse, mutect2, varscan2
- FGFR2 | c.424G>A p.D142N | Missense Mutation (SNP) | VAF 66/175 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as COSV60659230; called by muse, mutect2, varscan2
- FILIP1L | c.1268G>A p.R423K (on ENST00000354552 / NM_182909.3; = p.R183K on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV58765492, COSV58775965; called by muse, mutect2, varscan2
- FKBP5 | c.935C>T p.S312F | Missense Mutation (SNP) | VAF 88/142 reads (62%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.811); catalogued as COSV61883767; called by muse, mutect2, varscan2
- FLG | c.9524C>T p.S3175F | Missense Mutation (SNP) | VAF 370/660 reads (56%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs139489857; called by muse, mutect2, varscan2
- FOXK1 | c.728C>T p.S243F | Missense Mutation (SNP) | VAF 35/49 reads (71%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV61065108; called by muse, mutect2, varscan2
- FOXO3 | c.1205C>T p.S402L | Missense Mutation (SNP) | VAF 71/83 reads (86%) | SIFT tolerated (0.35); PolyPhen benign (0.121); catalogued as rs891060337, COSV59631240; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58565670; called by muse, mutect2
- FRAS1 | c.9202A>C p.I3068L | Missense Mutation (SNP) | VAF 83/139 reads (60%) | SIFT tolerated (0.15); PolyPhen benign (0.137); catalogued as COSV53646368; called by muse, mutect2, varscan2
- FRMD3 | c.1753G>A p.G585R | Missense Mutation (SNP) | VAF 122/275 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV100170976, COSV58469836; called by muse, mutect2, varscan2
- FRMPD2 | c.613A>G p.R205G | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as rs777392560, COSV59723613; called by mutect2, varscan2
- FRMPD4 | c.1667A>T p.Q556L | Missense Mutation (SNP) | VAF 104/117 reads (89%) | SIFT tolerated (0.32); PolyPhen benign (0.05); catalogued as COSV66223251; called by muse, mutect2, varscan2
- FRY | c.6002C>T p.A2001V | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.782); catalogued as COSV66580008; called by muse, mutect2, varscan2
- FYB2 | c.1004C>T p.S335L | Missense Mutation (SNP) | VAF 39/136 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs868676186, COSV58582820, COSV58583406; called by muse, mutect2, varscan2
- GALNT14 | c.242A>C p.Q81P | Missense Mutation (SNP) | VAF 125/158 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100204910; called by muse, mutect2, varscan2
- GALNT17 | c.1301G>A p.R434K | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV61169921; called by muse, mutect2, varscan2
- GALR1 | c.932G>A p.R311K | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.471); catalogued as COSV55319079; called by muse, mutect2, varscan2
- GATAD2B | c.206G>T p.G69V | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as COSV64086012; called by muse, mutect2
- GBA3 | c.965G>A p.G322E | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.45); PolyPhen benign (0.03); catalogued as COSV72438505; called by muse, mutect2, varscan2
- GDF3 | c.607G>A p.E203K | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV61712972; called by muse, mutect2, varscan2
- GFOD1 | c.872C>T p.P291L | Missense Mutation (SNP) | VAF 32/142 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs755452446, COSV64955365; called by muse, mutect2, varscan2
- GLP1R | c.364G>A p.D122N | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.64); PolyPhen benign (0.031); catalogued as COSV64716392; called by muse, mutect2, varscan2
- GLYAT | c.53T>C p.L18S | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53540651; called by muse, mutect2, varscan2
- GM2A | c.358C>T p.P120S | Missense Mutation (SNP) | VAF 66/84 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV64095901; called by muse, mutect2, varscan2
- GOLGA1 | c.124G>A p.G42R | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60617805; called by muse, mutect2, varscan2
- GP5 | c.131C>T p.S44F | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.033); catalogued as COSV55469368; called by muse, mutect2, varscan2
- GPR108 | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as COSV51187492, COSV99901522; called by muse, mutect2, varscan2
- GPR158 | c.3128C>T p.S1043F | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs1374104989, COSV66264976, COSV66273219; called by muse, mutect2, varscan2
- GPSM2 | c.416T>C p.V139A | Missense Mutation (SNP) | VAF 19/260 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.471); catalogued as COSV51443715, COSV99915348; called by muse, mutect2
- GPX5 | c.479C>T p.S160F | Missense Mutation (SNP) | VAF 71/240 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.152); catalogued as COSV69079841; called by muse, mutect2, varscan2
- GRIA2 | c.1831G>A p.D611N | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as rs1553956958, COSV52398829; ClinVar: not provided; called by muse, mutect2, varscan2
- GRID2 | c.1180C>T p.P394S | Missense Mutation (SNP) | VAF 35/68 reads (51%) | SIFT tolerated (0.91); PolyPhen benign (0.022); catalogued as COSV56193073; called by muse, mutect2, varscan2
- GRIN2B | c.4249G>A p.A1417T | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.5); PolyPhen benign (0.011); catalogued as rs866929842, COSV74206330; called by muse, mutect2, varscan2
- GRIN3A | c.1773G>A p.M591I | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.037); catalogued as rs865773972, COSV62458080; called by muse, mutect2
- GRIN3A | c.1433G>A p.W478* | Nonsense Mutation (SNP) | VAF 43/83 reads (52%) | catalogued as COSV62452041, COSV62458083; called by muse, mutect2, varscan2
- GSS | c.550C>T p.P184S | Missense Mutation (SNP) | VAF 43/97 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.411); catalogued as rs113191242, COSV53814441; called by muse, mutect2, varscan2
- GUCY2C | c.1711-1G>A p.X571_splice | Splice Site (SNP) | VAF 24/48 reads (50%) | catalogued as rs1209897808, COSV53795380; called by muse, mutect2, varscan2
- H6PD | c.527T>A p.F176Y | Missense Mutation (SNP) | VAF 80/133 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66232302; called by muse, mutect2, varscan2
- HABP2 | c.472C>T p.P158S | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63637952; called by muse, mutect2, varscan2
- HAPLN1 | c.497G>A p.R166Q | Missense Mutation (SNP) | VAF 25/33 reads (76%) | SIFT tolerated (0.28); PolyPhen benign (0.06); catalogued as rs773037636, COSV57145694; called by muse, mutect2, varscan2
- HCN1 | c.1003G>A p.E335K | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV57502899; called by muse, mutect2
- HCN4 | c.2326C>T p.P776S | Missense Mutation (SNP) | VAF 38/46 reads (83%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV56086834; called by muse, varscan2
- HDC | c.659G>A p.R220Q | Missense Mutation (SNP) | VAF 34/44 reads (77%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs772476286, COSV51076529; called by muse, mutect2, varscan2
- HIPK4 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 46/91 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.535); catalogued as COSV52525589; called by muse, mutect2, varscan2
- HKDC1 | c.1360G>A p.A454T | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1437619948, COSV100664607, COSV63576853; called by mutect2, varscan2
- HLA-DQB1 | c.580G>A p.E194K | Missense Mutation (SNP) | VAF 78/138 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66574759; called by muse, mutect2, varscan2
- HLTF | c.470G>A p.R157K | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1336213963, COSV59503650; called by muse, mutect2, varscan2
- HMGB4 | c.254G>A p.R85Q | Missense Mutation (SNP) | VAF 65/126 reads (52%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.9); catalogued as rs200510564, COSV53960970; called by muse, varscan2
- HMGN1 | c.266C>T p.S89F | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV55743186; called by muse, mutect2, varscan2
- HNRNPDL | c.568G>T p.G190* | Nonsense Mutation (SNP) | VAF 12/230 reads (5%) | catalogued as COSV55022534; called by muse, mutect2
- HNRNPR | c.299G>A p.G100E | Missense Mutation (SNP) | VAF 65/110 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV56424231; called by muse, mutect2, varscan2
- HOXA3 | c.352G>A p.A118T | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.69); PolyPhen benign (0.012); catalogued as COSV57828888; called by muse, mutect2, varscan2
- HPSE2 | c.1321-1G>T p.X441_splice | Splice Site (SNP) | VAF 14/50 reads (28%) | catalogued as COSV65181545, COSV65192119; called by mutect2, varscan2
- HTATSF1 | c.326C>T p.T109I | Missense Mutation (SNP) | VAF 26/30 reads (87%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV54481243; called by muse, mutect2, varscan2
- HTR2C | c.863G>A p.R288Q | Missense Mutation (SNP) | VAF 26/28 reads (93%) | SIFT tolerated (0.53); PolyPhen benign (0.141); catalogued as rs782814171, COSV52202906; called by muse, mutect2, varscan2
- HYDIN | c.9070C>T p.L3024F | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.323); catalogued as COSV99993089; called by muse, mutect2, varscan2
- IGFL2 | c.340A>G p.S114G (on ENST00000377693 / NM_001135113.2; = p.S125G on NM_001002915.2) | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.109); catalogued as COSV66617478; called by muse, mutect2, varscan2
- IGLV4-3 | c.179G>A p.G60E | Missense Mutation (SNP) | VAF 137/357 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.475); catalogued as rs768352202; called by muse, mutect2, varscan2
- IGSF1 | c.701C>T p.P234L | Missense Mutation (SNP) | VAF 19/29 reads (66%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV63840252; called by muse, mutect2, varscan2
- IGSF10 | c.136C>T p.R46W | Missense Mutation (SNP) | VAF 73/149 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750443709, COSV56791239; called by muse, mutect2, varscan2
- IGSF21 | c.610G>A p.G204S | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0.193); catalogued as rs199889644; called by muse, mutect2, varscan2
- IL1RL1 | c.1334T>G p.I445S | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV52120421; called by muse, mutect2, varscan2
- IL6ST | c.1046T>G p.L349R | Missense Mutation (SNP) | VAF 53/66 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61142892; called by muse, mutect2, varscan2
- ILDR1 | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 70/170 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV56550952; called by muse, mutect2, varscan2
- ING2 | c.745C>T p.P249S | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56564664; called by muse, mutect2, varscan2
- INHBA | c.607G>A p.E203K | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.845); catalogued as COSV54220749, COSV54225158; called by muse, mutect2, varscan2
- INPP5B | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 13/45 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.914); catalogued as COSV65958795; called by muse, mutect2, varscan2
- INSR | c.1562C>T p.P521L | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as rs761607332, COSV57173081; called by muse, mutect2, varscan2
- ITCH | c.1782-1G>A p.X594_splice (on ENST00000262650 / NM_001257137.3; = p.X553_splice on NM_031483.7 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 4/32 reads (13%) | catalogued as COSV52937113; called by mutect2, varscan2
- ITGBL1 | c.1054G>A p.G352R | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV66006214; called by muse, mutect2, varscan2
- ITIH5 | c.1366G>A p.G456S | Missense Mutation (SNP) | VAF 54/117 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1036096918, COSV53673587; called by muse, mutect2, varscan2
- ITPR1 | c.5500G>A p.G1834R (on ENST00000354582; = p.G1779R on NM_002222.7) | Missense Mutation (SNP) | VAF 57/68 reads (84%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); catalogued as COSV57003341; called by muse, mutect2, varscan2
- ITPR2 | c.6592C>T p.Q2198* | Nonsense Mutation (SNP) | VAF 34/114 reads (30%) | catalogued as rs1323331776, COSV67276019; called by muse, mutect2, varscan2
- JAKMIP1 | c.1171G>A p.D391N | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.229); catalogued as COSV51545206; called by muse, mutect2, varscan2
- JMJD1C | c.2390C>T p.P797L | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.864); catalogued as COSV67867510; called by muse, mutect2, varscan2
- KCNA10 | c.1301G>A p.G434E | Missense Mutation (SNP) | VAF 30/44 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63905320; called by muse, mutect2, varscan2
- KCNJ5 | c.725G>A p.R242Q | Missense Mutation (SNP) | VAF 62/73 reads (85%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as rs746240972, COSV57964945; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNQ3 | c.548G>A p.R183Q | Missense Mutation (SNP) | VAF 69/177 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs867625794, COSV66476278; called by muse, mutect2, varscan2
- KCTD16 | c.932C>T p.S311F | Missense Mutation (SNP) | VAF 60/69 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV72580547; called by muse, mutect2, varscan2
- KDM1A | c.919T>A p.L307M | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63090407; called by muse, mutect2, varscan2
- KDM3B | c.3724T>G p.S1242A | Missense Mutation (SNP) | VAF 67/78 reads (86%) | SIFT tolerated (0.18); PolyPhen benign (0.041); catalogued as COSV58695204; called by muse, mutect2, varscan2
- KDM6B | c.263G>A p.G88E | Missense Mutation (SNP) | VAF 29/37 reads (78%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.039); catalogued as rs1399016072, COSV99641682; called by muse, mutect2, varscan2
- KDM6B | c.1982G>A p.G661E | Missense Mutation (SNP) | VAF 61/71 reads (86%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.015); catalogued as COSV99641684; called by muse, mutect2, varscan2
- KIAA0319 | c.406G>A p.D136N | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.563); catalogued as COSV65501873; called by muse, mutect2, varscan2
- KIAA1109 | c.1808C>T p.S603F | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.564); catalogued as COSV52691691; called by muse, mutect2, varscan2
- KIAA1210 | c.851G>A p.G284E | Missense Mutation (SNP) | VAF 82/94 reads (87%) | SIFT tolerated (0.05); PolyPhen benign (0.136); catalogued as COSV68177234; called by muse, mutect2, varscan2
- KIAA1522 | c.1835C>T p.S612F (on ENST00000373480 / NM_001198972.2; = p.S671F on NM_020888.3) | Missense Mutation (SNP) | VAF 166/265 reads (63%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as rs1325161675, COSV53867875; called by muse, mutect2, varscan2
- KIF1A | c.2336C>T p.P779L | Missense Mutation (SNP) | VAF 26/32 reads (81%) | SIFT deleterious (0.01); PolyPhen benign (0.02); catalogued as COSV57501403; called by muse, mutect2, varscan2
- KIF22 | c.1873C>T p.H625Y | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.078); catalogued as COSV99361222; called by muse, mutect2, varscan2
- KIF3C | c.1265C>T p.P422L | Missense Mutation (SNP) | VAF 102/116 reads (88%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.54); catalogued as rs777980561, COSV53101792; called by muse, mutect2, varscan2
- KITLG | c.80G>A p.G27E | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.015); catalogued as COSV57202477, COSV57203977; called by muse, mutect2, varscan2
- KLB | c.1028G>A p.G343E | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV57305165; called by muse, mutect2, varscan2
- KLF17 | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 48/91 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); catalogued as COSV64857005; called by muse, mutect2, varscan2
- KLHDC7A | c.2001C>A p.D667E | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.258); catalogued as COSV101272796; called by muse, mutect2, varscan2
- KLHDC7A | c.2002C>G p.R668G | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV101272797, COSV68771013; called by muse, mutect2, varscan2
- KLRC1 | c.230G>A p.G77E | Missense Mutation (SNP) | VAF 48/129 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749131648, COSV61726031; called by muse, mutect2, varscan2
- KMT2A | c.5300C>T p.P1767L | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100629048; called by muse, mutect2, varscan2
- KRT23 | c.332G>A p.R111K | Missense Mutation (SNP) | VAF 70/81 reads (86%) | SIFT tolerated (0.17); PolyPhen benign (0.306); catalogued as COSV52928989; called by muse, mutect2, varscan2
- LAMA4 | c.3529G>A p.G1177R (on ENST00000230538 / NM_001105206.3; = p.G1170R on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57899439; called by muse, mutect2, varscan2
- LAMB4 | c.3106C>T p.P1036S | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT tolerated (0.82); PolyPhen benign (0.007); catalogued as rs1204414378, COSV99224371; called by muse, mutect2, varscan2
- LCE1F | c.308C>T p.S103F | Missense Mutation (SNP) | VAF 44/92 reads (48%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.648); catalogued as COSV57670242; called by muse, mutect2, varscan2
- LDLR | c.2423T>A p.L808H | Missense Mutation (SNP) | VAF 59/106 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV52945929; called by muse, mutect2, varscan2
- LENG8 | c.833C>T p.A278V | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as COSV100457634; called by muse, mutect2, varscan2
- LEPR | c.1106G>A p.W369* | Nonsense Mutation (SNP) | VAF 19/92 reads (21%) | catalogued as COSV60764327; called by muse, mutect2, varscan2
- LIFR | c.2993G>A p.G998E | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT tolerated (0.49); PolyPhen benign (0.116); catalogued as COSV54699662; called by muse, mutect2, varscan2
- LIPI | c.943G>A p.E315K | Missense Mutation (SNP) | VAF 49/94 reads (52%) | SIFT tolerated (0.91); PolyPhen benign (0.003); catalogued as COSV60708652; called by muse, mutect2, varscan2
- LONRF3 | c.488G>A p.G163E | Missense Mutation (SNP) | VAF 16/18 reads (89%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.969); catalogued as COSV59156883; called by muse, mutect2, varscan2
- LPA | c.5108C>T p.P1703L | Missense Mutation (SNP) | VAF 59/72 reads (82%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV60312043; called by muse, mutect2, varscan2
- LRIT1 | c.1521G>C p.K507N | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV64513528; called by muse, mutect2, varscan2
- LRP1 | c.4006G>A p.E1336K | Missense Mutation (SNP) | VAF 71/199 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.114); catalogued as rs1555184502, COSV54504078, COSV54525553; called by muse, mutect2, varscan2
- LRP1B | c.6092A>T p.K2031M | Missense Mutation (SNP) | VAF 26/41 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV67273434; called by muse, mutect2, varscan2
- LRP3 | c.2254C>T p.P752S | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.015); catalogued as COSV53507157; called by muse, mutect2
- LRRC31 | c.854G>A p.R285K | Missense Mutation (SNP) | VAF 44/103 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.059); catalogued as COSV52982957; called by muse, mutect2, varscan2
- LRRC66 | c.2091T>G p.C697W | Missense Mutation (SNP) | VAF 33/121 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.292); catalogued as COSV58636808; called by muse, mutect2, varscan2
- LRRIQ1 | c.1355A>T p.D452V | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT tolerated (0.52); PolyPhen benign (0.143); catalogued as COSV67838402; called by muse, mutect2, varscan2
- LRRIQ1 | c.2008A>G p.K670E | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV67838409; called by muse, mutect2, varscan2
- LRRIQ4 | c.934C>T p.Q312* | Nonsense Mutation (SNP) | VAF 25/56 reads (45%) | catalogued as COSV61620179; called by muse, mutect2, varscan2
- LTB | c.53C>T p.S18F | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as COSV53002261; called by muse, mutect2, varscan2
- LTBP2 | c.1567C>T p.L523F | Missense Mutation (SNP) | VAF 38/42 reads (90%) | SIFT tolerated (0.44); PolyPhen benign (0.063); catalogued as COSV56214026; called by muse, mutect2, varscan2
- LTN1 | c.365G>A p.R122Q | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1383229820, COSV63735236; called by muse, mutect2, varscan2
- LUZP2 | c.439T>G p.C147G | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61218495; called by muse, mutect2, varscan2
- LY6G6F-LY6G6D | c.485G>A p.G162E | Missense Mutation (SNP) | VAF 49/93 reads (53%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV101012205, COSV65443210; called by muse, mutect2, varscan2
- LY75 | c.5152C>T p.P1718S | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.643); catalogued as COSV55106898; called by muse, mutect2, varscan2
- LYST | c.2860C>T p.P954S | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.018); catalogued as rs770636769, COSV67703774; called by muse, mutect2, varscan2
- LYVE1 | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 76/138 reads (55%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV56283553, COSV99811183; called by muse, mutect2, varscan2
- MACC1 | c.743A>G p.E248G | Missense Mutation (SNP) | VAF 58/114 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV60546342; called by muse, mutect2, varscan2
- MAGEA11 | c.1006G>A p.E336K | Missense Mutation (SNP) | VAF 33/145 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.337); catalogued as COSV60756443; called by muse, varscan2
- MAGEB3 | c.835G>A p.A279T | Missense Mutation (SNP) | VAF 43/47 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV64397724; called by muse, mutect2, varscan2
- MAGEC1 | c.686C>T p.A229V | Missense Mutation (SNP) | VAF 74/85 reads (87%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as rs1304999958, COSV53568752; called by muse, mutect2, varscan2
- MAGEC1 | c.2287C>T p.P763S | Missense Mutation (SNP) | VAF 126/144 reads (88%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.235); catalogued as rs1161618613, COSV53581361; called by muse, mutect2, varscan2
- MAN1A2 | c.334C>T p.R112* | Nonsense Mutation (SNP) | VAF 25/58 reads (43%) | catalogued as rs1212306783, COSV62976746; called by muse, mutect2, varscan2
- MANBAL | c.73G>C p.G25R | Missense Mutation (SNP) | VAF 74/147 reads (50%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV65311445, COSV65311923; called by muse, mutect2, varscan2
- MAP1A | c.2011G>A p.E671K | Missense Mutation (SNP) | VAF 18/23 reads (78%) | SIFT tolerated (0.15); PolyPhen benign (0.292); catalogued as COSV55812494; called by muse, mutect2, varscan2
- MAP3K4 | c.4096G>A p.G1366R | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100815616, COSV62329900; called by muse, mutect2, varscan2
- MAPKBP1 | c.3991C>T p.P1331S (on ENST00000456763 / NM_001128608.2; = p.P1325S on NM_014994.3) | Missense Mutation (SNP) | VAF 70/78 reads (90%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV52961665; called by muse, mutect2, varscan2
- MDGA1 | c.650C>T p.S217F | Missense Mutation (SNP) | VAF 106/286 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs1199815132, COSV51801679; called by muse, mutect2, varscan2
- MDGA1 | c.361T>A p.S121T | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.735); catalogued as COSV51801701; called by muse, mutect2, varscan2
- MED13L | c.3833C>T p.A1278V | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs748882337, COSV56119547; called by muse, mutect2, varscan2
- MELK | c.1556C>T p.P519L | Missense Mutation (SNP) | VAF 29/34 reads (85%) | SIFT deleterious (0.01); PolyPhen benign (0.09); catalogued as COSV53202668; called by muse, mutect2, varscan2
- MELTF | c.590G>A p.G197E | Missense Mutation (SNP) | VAF 72/198 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.186); catalogued as COSV99586243; called by muse, mutect2, varscan2
- MELTF | c.589G>A p.G197R | Missense Mutation (SNP) | VAF 73/197 reads (37%) | SIFT tolerated (0.36); PolyPhen benign (0.017); catalogued as COSV56379566, COSV99586248; called by muse, mutect2, varscan2
- MFSD1 | c.944C>T p.P315L | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT tolerated (0.69); PolyPhen benign (0.058); catalogued as rs1225138029, COSV51843302; called by muse, mutect2, varscan2
- MGLL | c.302T>A p.L101* (on ENST00000398104 / NM_001003794.2; = p.L111* on NM_007283.6) | Nonsense Mutation (SNP) | VAF 43/153 reads (28%) | catalogued as COSV54030008; called by muse, mutect2, varscan2
- MICAL3 | c.4112C>T p.S1371F | Missense Mutation (SNP) | VAF 143/327 reads (44%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.118); catalogued as rs1003583573, COSV71588221, COSV71588227; called by muse, mutect2, varscan2
- MIER2 | c.349C>T p.P117S | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV53393961; called by muse, mutect2, varscan2
- MMEL1 | c.1933C>T p.R645W | Missense Mutation (SNP) | VAF 26/179 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs1179085007, COSV56526086; called by muse, mutect2, varscan2
- MMP15 | c.479C>T p.S160L | Missense Mutation (SNP) | VAF 105/158 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV54681527; called by muse, mutect2, varscan2
- MORN5 | c.4G>T p.E2* | Nonsense Mutation (SNP) | VAF 44/90 reads (49%) | catalogued as COSV65649737; called by muse, mutect2, varscan2
- MOXD1 | c.1144C>T p.H382Y | Missense Mutation (SNP) | VAF 29/32 reads (91%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); catalogued as COSV60949166; called by muse, mutect2, varscan2
- MROH2B | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 29/36 reads (81%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.562); catalogued as rs867084467, COSV68189387; called by muse, mutect2, varscan2
- MRPS18C | c.47T>C p.L16S | Missense Mutation (SNP) | VAF 48/319 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV55027907; called by muse, mutect2, varscan2
- MS4A10 | c.773G>A p.G258E | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.062); catalogued as COSV57633912; called by muse, mutect2, varscan2
- MSTN | c.1093C>T p.P365S | Missense Mutation (SNP) | VAF 22/26 reads (85%) | SIFT deleterious (0.01); PolyPhen benign (0.135); catalogued as COSV53621575; called by muse, mutect2, varscan2
- MTA2 | c.1718C>T p.S573F | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.086); catalogued as COSV53471387, COSV53471974, COSV99544924; called by muse, mutect2, varscan2
- MTHFD1 | c.323C>T p.S108F | Missense Mutation (SNP) | VAF 163/184 reads (89%) | SIFT deleterious (0.04); PolyPhen benign (0.312); catalogued as COSV53703748; called by muse, mutect2, varscan2
- MTRR | c.1732C>T p.P578S (on ENST00000264668; = p.P551S on NM_002454.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 95/109 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52942116, COSV52946781; called by muse, mutect2, varscan2
- MUC16 | c.38533C>T p.P12845S | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); catalogued as COSV67492622; called by muse, mutect2, varscan2
- MUC16 | c.38246C>T p.S12749F | Missense Mutation (SNP) | VAF 95/243 reads (39%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.8); catalogued as COSV67492625; called by muse, mutect2, varscan2
- MUC16 | c.37813A>G p.K12605E | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.033); catalogued as COSV101200162; called by muse, mutect2, varscan2
- MUC16 | c.28774C>A p.Q9592K | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.346); catalogued as rs765394492, COSV67492637; called by muse, mutect2, varscan2
- MUC16 | c.27953C>T p.T9318I | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.858); catalogued as COSV67492643; called by muse, mutect2, varscan2
- MUC16 | c.24191C>T p.S8064F | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.32); catalogued as COSV101200691, COSV67476204, COSV67492652; called by muse, mutect2, varscan2
- MUC16 | c.22048T>A p.S7350T | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.068); catalogued as COSV67492667; called by muse, mutect2, varscan2
- MUC16 | c.21106C>T p.P7036S | Missense Mutation (SNP) | VAF 44/113 reads (39%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.003); catalogued as rs1245163345, COSV67477246; called by muse, mutect2, varscan2
- MUC16 | c.9215A>G p.Q3072R | Missense Mutation (SNP) | VAF 47/99 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.503); catalogued as COSV67492689; called by muse, mutect2, varscan2
- MUC16 | c.1682C>T p.S561F | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.014); catalogued as COSV67462990; called by muse, mutect2
- MUC16 | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.135); catalogued as COSV67482671; called by muse, mutect2, varscan2
- MUC16 | c.217G>A p.G73R | Missense Mutation (SNP) | VAF 39/106 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.338); catalogued as rs1328059812, COSV67492709; called by muse, mutect2, varscan2
- MX1 | c.1321C>T p.R441C | Missense Mutation (SNP) | VAF 64/110 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.677); catalogued as rs757747473, COSV55820749; called by muse, mutect2, varscan2
- MYH1 | c.5642C>T p.S1881F | Missense Mutation (SNP) | VAF 121/136 reads (89%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as COSV56844220; called by muse, mutect2, varscan2
- MYH13 | c.5304G>A p.M1768I | Missense Mutation (SNP) | VAF 51/55 reads (93%) | SIFT tolerated (0.06); PolyPhen benign (0.02); catalogued as COSV52834160; called by muse, mutect2, varscan2
- MYH2 | c.380A>G p.N127S | Missense Mutation (SNP) | VAF 51/59 reads (86%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as rs748961733, COSV55447406; called by muse, mutect2, varscan2
- MYH7 | c.3937G>A p.E1313K | Missense Mutation (SNP) | VAF 50/58 reads (86%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV62523656; called by muse, mutect2, varscan2
- MYH7 | c.443G>A p.S148N | Missense Mutation (SNP) | VAF 161/181 reads (89%) | SIFT tolerated (0.08); PolyPhen benign (0.297); catalogued as CM034050, COSV62523660; called by muse, mutect2, varscan2
- MYO18B | c.6471G>A p.R2157= | Splice Region (SNP) | VAF 140/349 reads (40%) | catalogued as COSV59148138, COSV59148223; called by muse, mutect2, varscan2
- MYO1F | c.76C>T p.P26S | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV57800128; called by muse, mutect2, varscan2
- MYOC | c.640G>A p.E214K | Missense Mutation (SNP) | VAF 46/111 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs772953674, COSV50678747; called by muse, mutect2, varscan2
- MYOM2 | c.3517G>A p.E1173K | Missense Mutation (SNP) | VAF 67/157 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as COSV50771720; called by muse, mutect2, varscan2
- MYPN | c.2399C>T p.S800F | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.241); catalogued as COSV62739159; called by muse, mutect2, varscan2
- MYRIP | c.2522G>A p.R841K | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.007); catalogued as COSV56881291; called by muse, mutect2, varscan2
- MYT1 | c.3350G>A p.R1117K | Missense Mutation (SNP) | VAF 49/120 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60513263; called by muse, mutect2, varscan2
- NAA35 | c.1569-1G>A p.X523_splice | Splice Site (SNP) | VAF 24/61 reads (39%) | catalogued as COSV64486515; called by muse, mutect2, varscan2
- NACC2 | c.940C>T p.R314C | Missense Mutation (SNP) | VAF 66/144 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs747874789, COSV53202934; called by muse, mutect2, varscan2
- NAIF1 | c.817C>T p.Q273* | Nonsense Mutation (SNP) | VAF 18/47 reads (38%) | catalogued as COSV66092474; called by muse, mutect2, varscan2
- NAPSA | c.352T>C p.L118= | Splice Region (SNP) | VAF 9/200 reads (5%) | catalogued as COSV53799112; called by muse, mutect2
- NAT2 | c.242C>T p.T81I | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.398); catalogued as COSV99674102; called by muse, mutect2, varscan2
- NAV1 | c.4433C>T p.T1478I | Missense Mutation (SNP) | VAF 31/121 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); catalogued as rs914267810, COSV55226591; called by muse, mutect2, varscan2
- NBN | c.2006C>T p.S669F | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated (0.34); PolyPhen benign (0.159); catalogued as COSV55376926; called by muse, mutect2, varscan2
- NCEH1 | c.598C>T p.H200Y (on ENST00000538775; = p.H160Y on NM_020792.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 106/230 reads (46%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV56437731; called by muse, mutect2, varscan2
- NEB | c.14411C>A p.S4804Y | Missense Mutation (SNP) | VAF 101/130 reads (78%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV51424321, COSV51459301; called by muse, mutect2, varscan2
- NECTIN2 | c.1265C>T p.S422F | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV52980150; called by muse, mutect2, varscan2
- NEURL4 | c.572C>T p.A191V | Missense Mutation (SNP) | VAF 29/33 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs756985825, COSV59763257; called by muse, mutect2, varscan2
- NFE2 | c.1042G>A p.E348K | Missense Mutation (SNP) | VAF 48/132 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.13); catalogued as COSV56457316; called by muse, mutect2, varscan2
- NIM1K | c.204del p.K69Nfs*3 | Frame Shift Del (DEL) | VAF 9/84 reads (11%) | catalogued as COSV100389948; called by mutect2, varscan2
- NIM1K | c.701C>T p.P234L | Missense Mutation (SNP) | VAF 44/115 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); catalogued as COSV58145759; called by muse, mutect2, varscan2
- NKX2-5 | c.823C>T p.P275S | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.061); catalogued as rs368366482, CM033929, COSV61300040; called by muse, mutect2
- NLRP10 | c.485C>T p.P162L | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.44); PolyPhen benign (0.119); catalogued as COSV60782616; called by muse, mutect2, varscan2
- NLRP14 | c.556G>A p.G186R | Missense Mutation (SNP) | VAF 50/98 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55072283; called by muse, mutect2, varscan2
- NLRP8 | c.2759T>G p.L920R | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52593603; called by muse, mutect2, varscan2
- NLRP9 | c.570G>A p.M190I | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.03); catalogued as COSV60467719; called by muse, mutect2, varscan2
- NOP14 | c.2164C>T p.H722Y | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.966); catalogued as COSV58627718; called by muse, mutect2, varscan2
- NOS3 | c.1257C>G p.D419E | Missense Mutation (SNP) | VAF 38/242 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV52495554; called by muse, varscan2
- NPAP1 | c.2975G>A p.G992E | Missense Mutation (SNP) | VAF 36/39 reads (92%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.703); catalogued as rs763257404, COSV100276362, COSV61510981; called by muse, mutect2, varscan2
- NPY5R | c.259G>A p.D87N | Missense Mutation (SNP) | VAF 191/310 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58452952, COSV58453889; called by muse, mutect2, varscan2
- NR5A1 | c.395C>T p.P132L | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.142); catalogued as COSV101007702; called by muse, mutect2, varscan2
- NRG3 | c.1564G>A p.D522N | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.744); catalogued as COSV100931901, COSV64583509; called by muse, varscan2
- NUBP1 | c.517C>T p.P173S | Missense Mutation (SNP) | VAF 48/197 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV51595635; called by muse, mutect2, varscan2
- NUP107 | c.1642C>T p.R548C | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764034347, COSV57494858, COSV57495270; called by muse, mutect2, varscan2
- NUP98 | c.4555C>T p.P1519S (on ENST00000359171 / NM_001365126.1; = p.P1502S on NM_016320.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.551); catalogued as COSV61438280; called by muse, mutect2, varscan2
- NWD1 | c.832C>T p.L278F | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV100341844; called by muse, mutect2, varscan2
- NXF3 | c.706G>A p.D236N | Missense Mutation (SNP) | VAF 74/86 reads (86%) | SIFT tolerated (0.4); PolyPhen benign (0.01); catalogued as COSV67705110; called by muse, mutect2, varscan2
- NYAP2 | c.809A>C p.E270A | Missense Mutation (SNP) | VAF 97/114 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56016378; called by muse, mutect2, varscan2
- OBI1 | c.644G>T p.G215V | Missense Mutation (SNP) | VAF 30/53 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56147392; called by muse, mutect2, varscan2
- OCRL | c.50G>A p.G17D | Missense Mutation (SNP) | VAF 61/75 reads (81%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.665); catalogued as COSV63981859; called by muse, mutect2, varscan2
- OGA | c.2716C>T p.P906S | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as rs775460845, COSV63380945; called by muse, mutect2, varscan2
- OIT3 | c.793C>T p.P265S | Missense Mutation (SNP) | VAF 81/175 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV61827454; called by muse, mutect2, varscan2
- OLFM3 | c.704G>A p.G235E (on ENST00000338858 / NM_001288821.1; = p.G215E on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.999); catalogued as COSV58803568, COSV58803760; called by muse, mutect2, varscan2
- OR11H6 | c.841A>G p.T281A | Missense Mutation (SNP) | VAF 67/69 reads (97%) | SIFT tolerated (0.16); PolyPhen benign (0.247); catalogued as COSV59644756, COSV59645289; called by muse, mutect2, varscan2
- OR13C8 | c.295G>A p.V99M | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.04); catalogued as rs1381606091, COSV58612446; called by muse, mutect2, varscan2
- OR2B11 | c.335G>A p.G112E | Missense Mutation (SNP) | VAF 51/90 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV59511439; called by muse, mutect2, varscan2
- OR2F2 | c.628C>T p.P210S | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775804222, COSV101283821; called by muse, mutect2, varscan2
- OR2F2 | c.629C>T p.P210L | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370241192; called by muse, mutect2, varscan2
- OR2L2 | c.58T>C p.S20P | Missense Mutation (SNP) | VAF 83/190 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV63560728; called by muse, mutect2, varscan2
- OR2M3 | c.467G>A p.G156E | Missense Mutation (SNP) | VAF 74/145 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.253); catalogued as COSV71758873; called by muse, mutect2, varscan2
- OR51A4 | c.72T>G p.Y24* | Nonsense Mutation (SNP) | VAF 13/77 reads (17%) | catalogued as COSV100985270; called by muse, mutect2, varscan2
- OR51G1 | c.555G>C p.E185D | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.149); catalogued as COSV58970746; called by muse, mutect2, varscan2
- OR51L1 | c.880T>A p.Y294N | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58625773; called by muse, varscan2
- OR51L1 | c.919C>T p.H307Y | Missense Mutation (SNP) | VAF 23/33 reads (70%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV58625783; called by muse, varscan2
- OR51Q1 | c.911G>A p.G304E | Missense Mutation (SNP) | VAF 21/27 reads (78%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as rs764277738, COSV56180583; called by muse, mutect2, varscan2
- OR52B4 | c.656C>T p.S219F | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68769482; called by muse, mutect2
- OR56B1 | c.952C>T p.L318F | Missense Mutation (SNP) | VAF 36/68 reads (53%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs148131819; called by muse, mutect2, varscan2
- OR5H2 | c.806C>T p.S269F | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV62351857; called by muse, mutect2, varscan2
- OR6A2 | c.634C>T p.L212F | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT tolerated (0.15); PolyPhen probably damaging (1); catalogued as COSV60265863; called by muse, mutect2, varscan2
- OR7C1 | c.59C>T p.T20M | Missense Mutation (SNP) | VAF 14/192 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.411); catalogued as COSV99934899; called by muse, mutect2
- OR7C2 | c.467C>T p.S156F | Missense Mutation (SNP) | VAF 95/234 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.25); catalogued as rs867537184, COSV50180323; called by muse, mutect2, varscan2
- OR7C2 | c.875G>T p.R292M | Missense Mutation (SNP) | VAF 45/118 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); catalogued as COSV50182229, COSV99934551; called by muse, mutect2, varscan2
- OR7D4 | c.58G>A p.D20N | Missense Mutation (SNP) | VAF 41/103 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.029); catalogued as COSV58072224; called by muse, mutect2, varscan2
- OR8G1 | c.685C>T p.R229C | Missense Mutation (SNP) | VAF 25/29 reads (86%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.056); catalogued as rs368405472; called by muse, mutect2, varscan2
- OTOGL | c.5159C>T p.S1720L (on ENST00000547103; = p.S1711L on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV54023524; called by muse, mutect2, varscan2
- PALD1 | c.2080G>A p.V694M | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as rs1022510891, COSV54977237; called by muse, mutect2, varscan2
- PALMD | c.1028C>T p.P343L | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs760070084, COSV54165028; called by muse, mutect2, varscan2
- PAPPA2 | c.2118G>C p.K706N | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV62786494; called by muse, mutect2, varscan2
- PBX2 | c.1093G>A p.D365N | Missense Mutation (SNP) | VAF 61/118 reads (52%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.52); catalogued as rs1210876222, COSV66709402; called by muse, mutect2, varscan2
- PCDH11X | c.506G>A p.G169E | Missense Mutation (SNP) | VAF 28/30 reads (93%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV53503114; called by muse, mutect2, varscan2
- PCDHA4 | c.1861C>T p.P621S | Missense Mutation (SNP) | VAF 138/163 reads (85%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.417); catalogued as COSV63543109; called by muse, mutect2, varscan2
- PCDHA4 | c.2385+7G>T | Splice Region (SNP) | VAF 75/95 reads (79%) | catalogued as COSV63545890; called by muse, mutect2, varscan2
- PCDHA9 | c.199G>A p.D67N | Missense Mutation (SNP) | VAF 162/189 reads (86%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.088); catalogued as rs781827334, COSV65332512; called by muse, mutect2, varscan2
- PCDHGA1 | c.2008G>A p.D670N | Missense Mutation (SNP) | VAF 113/130 reads (87%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.082); catalogued as COSV65299100; called by muse, mutect2, varscan2
- PCDHGB1 | c.910G>A p.D304N | Missense Mutation (SNP) | VAF 105/114 reads (92%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs369227522; called by muse, mutect2, varscan2
- PCSK2 | c.1088C>T p.P363L | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as rs1012521327, COSV52742441; called by muse, mutect2, varscan2
- PDE6B | c.1470G>A p.K490= | Splice Region (SNP) | VAF 10/65 reads (15%) | catalogued as COSV55330818; called by muse, mutect2, varscan2
- PEX11B | c.725C>T p.S242F | Missense Mutation (SNP) | VAF 79/141 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV65199178; called by muse, mutect2, varscan2
- PGLYRP2 | c.1131G>A p.L377= | Splice Region (SNP) | VAF 99/258 reads (38%) | catalogued as rs762292256, COSV52997755; called by muse, mutect2, varscan2
- PGS1 | c.1485C>G p.H495Q | Missense Mutation (SNP) | VAF 42/50 reads (84%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.738); catalogued as rs1249019030, COSV53148570; called by muse, mutect2, varscan2
- PHF21B | c.128G>A p.G43E | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57562158; called by muse, mutect2, varscan2
- PHF3 | c.481G>A p.A161T | Missense Mutation (SNP) | VAF 98/438 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs756957709, COSV50340865; called by muse, mutect2, varscan2
- PHOSPHO2 | c.226C>T p.P76S | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.053); catalogued as COSV55869574; called by muse, mutect2, varscan2
- PHYHIP | c.884C>T p.S295F | Missense Mutation (SNP) | VAF 123/287 reads (43%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.807); catalogued as COSV58689403; called by muse, mutect2, varscan2
- PIGU | c.220C>T p.H74Y | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.816); catalogued as COSV54166388; called by muse, mutect2, varscan2
- PIK3CB | c.2539C>T p.R847C | Missense Mutation (SNP) | VAF 52/89 reads (58%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.893); catalogued as rs759151757, COSV56687932, COSV56689539; called by muse, mutect2, varscan2
- PKHD1L1 | c.5947C>T p.H1983Y | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.393); catalogued as COSV65752735; called by muse, mutect2, varscan2
- PKIA | c.221C>T p.S74F | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV61916693; called by muse, mutect2, varscan2
- PLA2G2C | c.422G>A p.R141K | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.28); PolyPhen benign (0.136); catalogued as COSV56124488, COSV56125135; called by muse, mutect2, varscan2
- PLA2G2F | c.88G>A p.G30R | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs771680765, COSV64280366; called by muse, mutect2, varscan2
- PLCB1 | c.1427G>T p.G476V | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.02); catalogued as COSV62067951, COSV62071491; called by muse, mutect2, varscan2
- PLCB4 | c.2074G>A p.E692K | Missense Mutation (SNP) | VAF 115/316 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV53803703; called by muse, mutect2, varscan2
- PLCG2 | c.3247C>T p.P1083S | Missense Mutation (SNP) | VAF 52/77 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100842647, COSV63876169; called by muse, mutect2, varscan2
- PLEC | c.5974G>A p.A1992T (on ENST00000322810 / NM_201380.4; = p.A1882T on NM_000445.5) | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.817); catalogued as rs566759064, COSV59694150; called by muse, mutect2
- PLIN4 | c.1415G>A p.G472D (on ENST00000301286; = p.G487D on NM_001367868.2) | Missense Mutation (SNP) | VAF 59/156 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.365); catalogued as COSV56698578; called by muse, mutect2, varscan2
- PLOD1 | c.1675C>T p.P559S | Missense Mutation (SNP) | VAF 107/215 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs576500420, COSV52150323; called by muse, mutect2, varscan2
- PLXNA4 | c.2482G>A p.G828S | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as COSV58159526; called by muse, mutect2, varscan2
- PLXNB1 | c.5143A>T p.K1715* | Nonsense Mutation (SNP) | VAF 207/243 reads (85%) | catalogued as COSV56494120; called by muse, mutect2, varscan2
- PNMA5 | c.388C>T p.P130S | Missense Mutation (SNP) | VAF 132/145 reads (91%) | SIFT tolerated (0.23); PolyPhen benign (0.045); catalogued as COSV62626273; called by muse, mutect2, varscan2
- POTEF | c.2285G>A p.R762K | Missense Mutation (SNP) | VAF 115/146 reads (79%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.066); catalogued as COSV62544246; called by muse, mutect2, varscan2
- POU2F3 | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 44/54 reads (81%) | SIFT tolerated (0.05); PolyPhen benign (0.073); catalogued as COSV52795007; called by muse, mutect2, varscan2
- PRADC1 | c.442G>A p.D148N | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.994); catalogued as COSV57820931; called by muse, mutect2, varscan2
- PRAMEF12 | c.98G>T p.R33M | Missense Mutation (SNP) | VAF 57/119 reads (48%) | SIFT tolerated (0.47); PolyPhen benign (0.015); catalogued as COSV63215648; called by muse, mutect2, varscan2
- PRAMEF17 | c.931G>A p.E311K | Missense Mutation (SNP) | VAF 100/518 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV101068742; called by muse, mutect2, varscan2
- PREX2 | c.770C>T p.S257F | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.212); catalogued as COSV55798117; called by muse, mutect2, varscan2
- PRKAA2 | c.1325G>A p.R442K | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV64802198; called by muse, mutect2, varscan2
- PRKD3 | c.95C>T p.P32L | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.052); catalogued as COSV99306280; called by muse, mutect2
- PRR12 | c.988G>A p.G330S (on ENST00000615927; = p.G1151S on NM_020719.3) | Missense Mutation (SNP) | VAF 13/17 reads (76%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as rs1461805873, COSV101330697; called by muse, mutect2, varscan2
- PRR12 | c.1814C>T p.P605L (on ENST00000615927; = p.P1426L on NM_020719.3) | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.007); catalogued as rs1395182917, COSV69818314; called by muse, mutect2, varscan2
- PRR5-ARHGAP8 | c.1258C>T p.P420S (on ENST00000352766; = p.P341S on NM_181334.5) | Missense Mutation (SNP) | VAF 72/147 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV61237319; called by muse, mutect2, varscan2
- PRR5L | c.764C>T p.S255F | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.326); catalogued as COSV61123483; called by muse, mutect2, varscan2
- PRRC2A | c.497C>T p.S166F | Missense Mutation (SNP) | VAF 71/142 reads (50%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as COSV63225023; called by muse, mutect2, varscan2
- PRRC2A | c.2902C>T p.P968S | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs781692538, COSV65688921; called by mutect2, varscan2
- PRSS12 | c.1022C>T p.P341L | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.338); catalogued as rs1422687981, COSV56610274; called by muse, mutect2, varscan2
- PRTG | c.1034G>A p.R345Q | Missense Mutation (SNP) | VAF 43/55 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1567096090, COSV66837474; called by muse, mutect2, varscan2
- PRUNE2 | c.6761G>A p.S2254N | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV65047770; called by muse, mutect2, varscan2
- PRX | c.2002C>T p.P668S | Missense Mutation (SNP) | VAF 64/155 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52533346; called by muse, mutect2, varscan2
- PSD3 | c.407C>T p.S136L | Missense Mutation (SNP) | VAF 108/234 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.251); catalogued as rs757971150, COSV58979080; called by muse, mutect2, varscan2
- PSMA7 | c.655-1G>T p.X219_splice | Splice Site (SNP) | VAF 22/58 reads (38%) | catalogued as COSV99444109; called by muse, varscan2
- PSMD3 | c.473C>T p.P158L | Missense Mutation (SNP) | VAF 191/219 reads (87%) | SIFT deleterious (0.02); PolyPhen benign (0.109); catalogued as COSV52859692; called by muse, mutect2, varscan2
- PTCHD3 | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 51/151 reads (34%) | SIFT tolerated (0.49); PolyPhen benign (0.054); catalogued as COSV71256317; called by muse, mutect2, varscan2
- PTGER1 | c.1117A>C p.K373Q | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.017); catalogued as COSV52876518; called by muse, mutect2, varscan2
- PTPN1 | c.1157C>T p.S386F | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs778546018, COSV50403876; called by muse, mutect2, varscan2
- PTX4 | c.1295G>A p.R432Q (on ENST00000447419 / NM_001328608.2; = p.R427Q on NM_001013658.1) | Missense Mutation (SNP) | VAF 60/109 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.736); catalogued as rs376527944; called by muse, mutect2, varscan2
- PWWP3B | c.934A>C p.S312R | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT tolerated (0.39); PolyPhen benign (0.025); catalogued as COSV61801696; called by muse, mutect2, varscan2
- PXDNL | c.4132G>A p.A1378T | Missense Mutation (SNP) | VAF 48/102 reads (47%) | SIFT tolerated (0.52); PolyPhen benign (0.028); catalogued as COSV62487574; called by muse, varscan2
- PXDNL | c.4085C>T p.S1362F | Missense Mutation (SNP) | VAF 42/104 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as COSV62498193; called by muse, varscan2
- PXDNL | c.1447C>T p.Q483* | Nonsense Mutation (SNP) | VAF 155/379 reads (41%) | catalogued as COSV62498195; called by muse, mutect2, varscan2
- PYGM | c.1451C>T p.T484I | Missense Mutation (SNP) | VAF 124/394 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51228022; called by muse, mutect2, varscan2
- RAB3GAP1 | c.2848C>T p.P950S | Missense Mutation (SNP) | VAF 37/133 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.433); catalogued as rs200519153, COSV51488596; called by muse, mutect2, varscan2
- RABL3 | c.421C>T p.P141S | Missense Mutation (SNP) | VAF 212/504 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV56337908; called by muse, mutect2, varscan2
- RAD9A | c.930G>A p.M310I | Missense Mutation (SNP) | VAF 30/119 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); catalogued as COSV57238232; called by muse, mutect2, varscan2
- RAG1 | c.938G>A p.C313Y | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV55028121; called by muse, mutect2, varscan2
- RALGAPA1 | c.5538A>G p.V1846= | Splice Region (SNP) | VAF 10/14 reads (71%) | catalogued as COSV51896341; called by mutect2, varscan2
- RANBP2 | c.508C>T p.R170W | Missense Mutation (SNP) | VAF 158/397 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs747511680, COSV51708594; called by muse, mutect2, varscan2
- RANBP3 | c.1099+1G>A p.X367_splice (on ENST00000340578 / NM_007322.3; = p.X362_splice on NM_003624.3) | Splice Site (SNP) | VAF 22/49 reads (45%) | catalogued as COSV99222341; called by muse, mutect2, varscan2
- RANBP3 | c.1099G>A p.E367K (on ENST00000340578 / NM_007322.3; = p.E362K on NM_003624.3) | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.543); catalogued as COSV99222342; called by muse, mutect2, varscan2
- RAPGEF3 | c.1759G>A p.A587T (on ENST00000389212; = p.A545T on NM_006105.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV50238189; called by muse, mutect2, varscan2
- RELN | c.1176T>A p.Y392* | Nonsense Mutation (SNP) | VAF 62/97 reads (64%) | catalogued as COSV59033092; called by muse, mutect2, varscan2
- RERE | c.4045C>T p.R1349W | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.533); catalogued as rs1488007934, COSV61947836; called by muse, mutect2, varscan2
- RESF1 | c.5080G>A p.E1694K | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.031); catalogued as COSV57025592; called by muse, mutect2, varscan2
- RGL1 | c.632C>T p.S211F (on ENST00000360851 / NM_001297672.2; = p.S246F on NM_015149.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.047); catalogued as rs1014911536, COSV58996146; called by muse, mutect2, varscan2
- RHEX | c.302C>T p.S101L | Missense Mutation (SNP) | VAF 228/253 reads (90%) | SIFT tolerated (0.19); PolyPhen benign (0.141); catalogued as rs537162083, COSV58979966; called by muse, mutect2, varscan2
- RIMS1 | c.4111C>T p.R1371C | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs995769455, COSV53465041; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RNF112 | c.1088G>A p.G363E | Missense Mutation (SNP) | VAF 32/36 reads (89%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV101465416; called by muse, mutect2, varscan2
- RNF183 | c.200C>T p.S67L | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as COSV52907931; called by muse, mutect2, varscan2
- ROBO2 | c.2084G>A p.R695Q | Missense Mutation (SNP) | VAF 21/24 reads (88%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.971); catalogued as COSV59923540; called by muse, mutect2, varscan2
- ROPN1B | c.110G>A p.G37E | Missense Mutation (SNP) | VAF 43/99 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.034); catalogued as COSV52543245; called by muse, mutect2, varscan2
- RORC | c.1203T>A p.F401L | Missense Mutation (SNP) | VAF 41/104 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.943); catalogued as COSV59095592; called by muse, mutect2, varscan2
- ROS1 | c.4705C>T p.R1569W | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.251); catalogued as rs199762082, COSV63861548; called by muse, mutect2, varscan2
- ROS1 | c.1102T>A p.L368I | Missense Mutation (SNP) | VAF 22/29 reads (76%) | SIFT tolerated (0.53); PolyPhen benign (0.058); catalogued as COSV63856828; called by muse, mutect2, varscan2
- RP1 | c.110G>A p.R37Q | Missense Mutation (SNP) | VAF 63/125 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as rs1454376137, COSV55112816; called by muse, mutect2, varscan2
- RPGR | c.1572+1G>A p.X524_splice | Splice Site (SNP) | VAF 13/19 reads (68%) | catalogued as CS067114, COSV100140085; called by muse, mutect2, varscan2
- RPGR | c.1572G>A p.K524= | Splice Region (SNP) | VAF 13/19 reads (68%) | catalogued as COSV100140087; called by muse, mutect2, varscan2
- RPS6KA6 | c.1861C>T p.P621S | Missense Mutation (SNP) | VAF 14/16 reads (88%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53126477; called by mutect2, varscan2
- RSL24D1 | c.340A>G p.K114E | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.996); catalogued as COSV53066236; called by muse, mutect2, varscan2
- RSPO4 | c.368C>T p.P123L | Missense Mutation (SNP) | VAF 69/159 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370909673; called by muse, mutect2, varscan2
- RTTN | c.2672T>G p.V891G | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.447); catalogued as COSV55351982; called by muse, mutect2, varscan2
- RTTN | c.1932A>T p.E644D | Missense Mutation (SNP) | VAF 42/82 reads (51%) | SIFT tolerated (0.76); PolyPhen benign (0.006); catalogued as COSV55351992; called by muse, mutect2, varscan2
- RXFP1 | c.1724G>A p.G575E | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV57046214, COSV57056510; called by muse, mutect2, varscan2
- SAGE1 | c.766G>A p.E256K | Missense Mutation (SNP) | VAF 66/74 reads (89%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.737); catalogued as COSV61011928; called by muse, mutect2, varscan2
- SASH1 | c.2041C>T p.P681S | Missense Mutation (SNP) | VAF 40/52 reads (77%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV66565817; called by muse, mutect2, varscan2
- SBNO2 | c.2656G>A p.A886T | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as COSV62323570; called by muse, mutect2, varscan2
- SCLY | c.1097C>T p.T366I (on ENST00000651534; = p.T358I on NM_016510.7) | Missense Mutation (SNP) | VAF 13/121 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); catalogued as COSV54544325; called by muse, mutect2, varscan2
- SDK1 | c.1124G>T p.R375M | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.721); catalogued as COSV67388176; called by muse, mutect2, varscan2
- SDK1 | c.4976C>T p.S1659L | Missense Mutation (SNP) | VAF 104/286 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1562391075, COSV67357900; called by muse, mutect2, varscan2
- SEC31A | c.242C>T p.S81F | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.195); catalogued as COSV58881019; called by muse, mutect2, varscan2
- SEC31B | c.1135A>T p.K379* | Nonsense Mutation (SNP) | VAF 151/326 reads (46%) | catalogued as COSV64825155; called by muse, mutect2, varscan2
- SECISBP2 | c.1045C>T p.P349S | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as rs369857385, COSV60530127; called by muse, mutect2, varscan2
- SERPINA6 | c.280G>A p.G94S | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.892); catalogued as COSV58587527; called by muse, mutect2, varscan2
- SF3B3 | c.104G>T p.G35V | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); catalogued as COSV56790988; called by muse, mutect2, varscan2
- SFMBT2 | c.368T>C p.V123A | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV62816486; called by muse, mutect2, varscan2
- SFRP1 | c.862G>A p.D288N | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.152); catalogued as COSV55177395; called by muse, mutect2, varscan2
- SFXN5 | c.556C>T p.Q186* | Nonsense Mutation (SNP) | VAF 22/26 reads (85%) | catalogued as COSV55590621; called by muse, mutect2, varscan2
- SGK3 | c.62C>T p.S21F | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.08); catalogued as rs1427992514, COSV61896787; called by muse, mutect2, varscan2
- SGMS1 | c.927G>A p.W309* | Nonsense Mutation (SNP) | VAF 21/56 reads (38%) | catalogued as COSV62373093; called by muse, mutect2, varscan2
- SH2B2 | c.1492G>A p.V498M | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782671132, COSV60825780; called by muse, mutect2, varscan2
- SH3BP1 | c.1939C>T p.P647S | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.001); catalogued as COSV53217501; called by muse, mutect2
- SH3GL2 | c.928G>A p.G310R | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV66051126; called by muse, mutect2, varscan2
- SHANK2 | c.3917C>T p.S1306F | Missense Mutation (SNP) | VAF 46/163 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); catalogued as rs1209297711, COSV53618272; called by muse, mutect2, varscan2
- SHROOM4 | c.3068T>A p.L1023H | Missense Mutation (SNP) | VAF 13/16 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV56797034; called by muse, mutect2, varscan2
- SIGLEC11 | c.226G>A p.G76R | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as COSV70222046; called by muse, mutect2, varscan2
- SIGLEC14 | c.415G>A p.V139M | Missense Mutation (SNP) | VAF 58/178 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55779153, COSV55783856; called by muse, mutect2, varscan2
- SIGLEC6 | c.704C>T p.S235F | Missense Mutation (SNP) | VAF 74/182 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.463); catalogued as rs769390343, COSV58437398; called by muse, mutect2, varscan2
- SIGLEC7 | c.467G>A p.G156D | Missense Mutation (SNP) | VAF 120/279 reads (43%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.943); catalogued as COSV58317800; called by muse, mutect2, varscan2
- SIM1 | c.1270G>A p.D424N | Missense Mutation (SNP) | VAF 53/62 reads (85%) | SIFT deleterious (0.03); PolyPhen benign (0.072); catalogued as rs763972030, COSV53490592; called by muse, mutect2, varscan2
- SIRPB2 | c.277C>T p.P93S | Missense Mutation (SNP) | VAF 44/100 reads (44%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV63125341; called by muse, mutect2, varscan2
- SLAMF8 | c.680G>A p.G227E | Missense Mutation (SNP) | VAF 261/485 reads (54%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.69); catalogued as COSV56989884; called by muse, mutect2, varscan2
- SLC10A3 | c.464C>T p.A155V | Missense Mutation (SNP) | VAF 56/72 reads (78%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs376734599, COSV54837470; called by muse, mutect2, varscan2
- SLC15A2 | c.1310C>T p.S437F | Missense Mutation (SNP) | VAF 47/246 reads (19%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as COSV55196288; called by muse, mutect2, varscan2
- SLC16A9 | c.578C>T p.S193F | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as rs752716124, COSV68100588; called by muse, mutect2, varscan2
- SLC17A8 | c.1543C>T p.L515F | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.19); catalogued as COSV60123113, COSV60124368; called by muse, mutect2, varscan2
- SLC18A1 | c.989C>T p.T330I | Missense Mutation (SNP) | VAF 64/141 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52351202; called by muse, mutect2, varscan2
- SLC24A3 | c.122C>T p.S41L | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.018); catalogued as COSV100041488; called by muse, mutect2, varscan2
- SLC24A3 | c.832G>A p.G278R | Missense Mutation (SNP) | VAF 57/172 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.16); catalogued as rs371903812; called by muse, mutect2, varscan2
- SLC25A45 | c.152C>T p.S51F | Missense Mutation (SNP) | VAF 43/75 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV53684169, COSV99587347; called by muse, mutect2, varscan2
- SLC2A9 | c.1003-1G>A p.X335_splice | Splice Site (SNP) | VAF 12/40 reads (30%) | catalogued as COSV53324521, COSV53328512; called by muse, mutect2
- SLC39A10 | c.2389C>T p.P797S | Missense Mutation (SNP) | VAF 6/138 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.082); catalogued as COSV56785405; called by muse, mutect2
- SLC44A2 | c.1283A>T p.Q428L | Missense Mutation (SNP) | VAF 50/110 reads (45%) | SIFT tolerated (0.82); PolyPhen benign (0.003); catalogued as rs1343831487, COSV59838996; called by muse, mutect2, varscan2
- SLC6A13 | c.1261C>T p.L421F | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.583); catalogued as COSV58256767; called by muse, mutect2, varscan2
- SLC6A6 | c.757C>T p.P253S | Missense Mutation (SNP) | VAF 120/144 reads (83%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV62651808; called by muse, mutect2, varscan2
- SLC9A2 | c.460G>T p.G154C | Missense Mutation (SNP) | VAF 297/380 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52137779; called by muse, mutect2, varscan2
- SLCO1B3 | c.796G>A p.G266R | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53943829, COSV53946131; called by muse, mutect2, varscan2
- SLCO3A1 | c.635C>T p.S212L | Missense Mutation (SNP) | VAF 12/15 reads (80%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as rs1346734459, COSV59230404; called by muse, mutect2, varscan2
- SLCO4A1 | c.308A>G p.K103R | Missense Mutation (SNP) | VAF 43/107 reads (40%) | SIFT tolerated (0.51); PolyPhen benign (0.02); catalogued as COSV53894079; called by muse, mutect2, varscan2
- SLF1 | c.2632C>G p.P878A | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99476022; called by muse, mutect2, varscan2
- SLF1 | c.2633C>T p.P878L | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99476025; called by muse, mutect2, varscan2
- SLIT2 | c.2144G>A p.G715E | Missense Mutation (SNP) | VAF 162/273 reads (59%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.735); catalogued as COSV56567437; called by muse, mutect2, varscan2
- SLITRK3 | c.2164G>A p.G722S | Missense Mutation (SNP) | VAF 60/97 reads (62%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.934); catalogued as COSV53853310; called by muse, mutect2, varscan2
- SMARCA4 | c.808C>T p.P270S | Missense Mutation (SNP) | VAF 41/91 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0.166); catalogued as COSV60795168; called by muse, mutect2, varscan2
- SMO | c.1834G>A p.A612T | Missense Mutation (SNP) | VAF 110/194 reads (57%) | SIFT tolerated (0.49); PolyPhen benign (0.091); catalogued as COSV50843133; called by muse, mutect2, varscan2
- SNAI3 | c.514C>T p.Q172* | Nonsense Mutation (SNP) | VAF 84/127 reads (66%) | catalogued as COSV60003419; called by muse, mutect2, varscan2
- SNCG | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 43/86 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.926); catalogued as COSV62318407; called by muse, mutect2, varscan2
- SNRNP200 | c.4778C>T p.T1593I | Missense Mutation (SNP) | VAF 59/73 reads (81%) | SIFT deleterious (0.05); PolyPhen benign (0.012); catalogued as COSV60494456; called by muse, mutect2, varscan2
- SOAT2 | c.1340C>T p.P447L | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56861271; called by muse, mutect2, varscan2
- SORBS1 | c.3530C>T p.P1177L | Missense Mutation (SNP) | VAF 66/174 reads (38%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); catalogued as COSV53365170; called by muse, mutect2, varscan2
- SORCS3 | c.1606G>C p.G536R | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63818250, COSV63824241, COSV63826077; called by muse, mutect2, varscan2
- SOX10 | c.844A>G p.S282G | Missense Mutation (SNP) | VAF 14/433 reads (3%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); catalogued as rs1446842498, COSV62807471; called by muse, mutect2
- SPATA31E1 | c.2194G>A p.E732K | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs780597687, COSV100350624, COSV57789681; called by muse, mutect2, varscan2
- SPATA31E1 | c.2195A>C p.E732A | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.41); PolyPhen benign (0.006); catalogued as COSV100350578; called by muse, mutect2, varscan2
- SPATA5L1 | c.1951C>T p.P651S | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); catalogued as COSV59745603; called by muse, mutect2, varscan2
- SPDL1 | c.589C>T p.L197F | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.42); PolyPhen benign (0.015); catalogued as COSV54669752; called by muse, mutect2, varscan2
- SPSB4 | c.715G>A p.D239N | Missense Mutation (SNP) | VAF 47/91 reads (52%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.762); catalogued as COSV60150364; called by muse, mutect2, varscan2
- SRCAP | c.3019C>T p.R1007W | Missense Mutation (SNP) | VAF 59/188 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs970002773, COSV52677778; called by muse, varscan2
- SRGAP1 | c.1502C>T p.T501I | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs1390382975, COSV61903398; called by muse, mutect2, varscan2
- ST6GALNAC4 | c.766C>T p.R256W | Missense Mutation (SNP) | VAF 41/112 reads (37%) | PolyPhen benign (0.115); catalogued as rs768063268, COSV59130679; called by muse, mutect2, varscan2
- STAMBP | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 37/53 reads (70%) | SIFT tolerated (0.27); PolyPhen benign (0.045); catalogued as COSV59898394; called by muse, mutect2, varscan2
- STEAP3 | c.520G>A p.A174T | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV61531009; called by muse, mutect2, varscan2
- STIMATE | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 48/60 reads (80%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as rs1022891167, COSV61890739, COSV61891640; called by muse, mutect2, varscan2
- STK31 | c.1092G>A p.M364I | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as COSV63454200; called by muse, mutect2, varscan2
- STRN | c.1213_1215del p.S405del | In Frame Del (DEL) | VAF 57/213 reads (27%) | catalogued as rs755625860; called by pindel, varscan2
- STT3B | c.368T>C p.L123S | Missense Mutation (SNP) | VAF 34/46 reads (74%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV55505954; called by muse, mutect2, varscan2
- SUN3 | c.1036C>T p.R346* | Nonsense Mutation (SNP) | VAF 57/212 reads (27%) | catalogued as rs200449194, COSV52050331; called by muse, mutect2, varscan2
- SUPT16H | c.35G>T p.R12L | Missense Mutation (SNP) | VAF 46/59 reads (78%) | SIFT deleterious (0.01); PolyPhen benign (0.133); catalogued as COSV53527710; called by muse, mutect2, varscan2
- SUPT6H | c.900C>T p.L300= | Splice Region (SNP) | VAF 87/213 reads (41%) | catalogued as COSV58931385; called by muse, mutect2, varscan2
- SUSD6 | c.349C>T p.P117S | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs774380392, COSV61366804; called by muse, mutect2, varscan2
- SV2B | c.1855C>T p.P619S | Missense Mutation (SNP) | VAF 21/28 reads (75%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs150512068; called by muse, mutect2, varscan2
- SVOP | c.1579C>T p.Q527* | Nonsense Mutation (SNP) | VAF 134/344 reads (39%) | catalogued as COSV54468892; called by muse, mutect2, varscan2
- SVOP | c.1176G>A p.W392* | Nonsense Mutation (SNP) | VAF 3/15 reads (20%) | catalogued as rs1162358560, COSV54468906; called by muse, mutect2
- SYCP1 | c.1760G>A p.R587K | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated (0.09); PolyPhen benign (0.025); catalogued as COSV65697082, COSV65700903; called by muse, mutect2
- SYCP1 | c.2383-1G>T p.X795_splice | Splice Site (SNP) | VAF 5/18 reads (28%) | catalogued as COSV65700906; called by muse, mutect2, varscan2
- SYNE2 | c.3190C>T p.P1064S | Missense Mutation (SNP) | VAF 13/17 reads (76%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV59969528; called by muse, mutect2, varscan2
- SYNGR4 | c.668C>T p.P223L | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.922); catalogued as COSV61226037; called by muse, mutect2, varscan2
- SYNPO2 | c.2599G>A p.G867R | Missense Mutation (SNP) | VAF 59/214 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as COSV61115895, COSV61116889; called by muse, mutect2, varscan2
- SYNPR | c.745G>A p.D249N | Missense Mutation (SNP) | VAF 17/20 reads (85%) | SIFT tolerated (0.5); PolyPhen benign (0.023); catalogued as rs1359750817, COSV55730601; called by muse, mutect2, varscan2
- SYT16 | c.1414G>A p.E472K | Missense Mutation (SNP) | VAF 15/17 reads (88%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as rs761577435, COSV70859850; called by muse, mutect2, varscan2
- TAAR5 | c.594A>T p.K198N | Missense Mutation (SNP) | VAF 44/50 reads (88%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV57799872; called by muse, mutect2, varscan2
- TAS2R46 | c.649C>T p.Q217* | Nonsense Mutation (SNP) | VAF 25/64 reads (39%) | catalogued as COSV67862521; called by muse, mutect2, varscan2
- TBC1D2 | c.2119C>T p.P707S | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV59788782; called by muse, mutect2, varscan2
- TDRD5 | c.47G>A p.R16K | Missense Mutation (SNP) | VAF 73/282 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54250255; called by muse, mutect2, varscan2
- TDRD6 | c.2786C>T p.S929L | Missense Mutation (SNP) | VAF 36/144 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.226); catalogued as COSV60178536; called by muse, mutect2, varscan2
- TECTA | c.3688C>T p.P1230S | Missense Mutation (SNP) | VAF 21/29 reads (72%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.999); catalogued as COSV50802889; called by muse, mutect2, varscan2
- TEF | c.410C>T p.S137F | Missense Mutation (SNP) | VAF 53/101 reads (52%) | SIFT tolerated (0.08); PolyPhen benign (0.178); catalogued as COSV56748900; called by muse, mutect2, varscan2
- TENM3 | c.2504A>C p.K835T | Missense Mutation (SNP) | VAF 38/68 reads (56%) | SIFT deleterious (0.03); PolyPhen benign (0.038); catalogued as COSV69318991; called by muse, mutect2, varscan2
- TENM3 | c.5321T>A p.L1774H | Missense Mutation (SNP) | VAF 14/21 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as COSV69318995; called by muse, mutect2, varscan2
- TEPP | c.100A>G p.T34A | Missense Mutation (SNP) | VAF 43/83 reads (52%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV52044413; called by muse, mutect2, varscan2
- TGM1 | c.2420A>G p.E807G | Missense Mutation (SNP) | VAF 72/82 reads (88%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.431); catalogued as COSV52865444; called by muse, mutect2, varscan2
- TGM2 | c.539G>A p.W180* | Nonsense Mutation (SNP) | VAF 142/350 reads (41%) | catalogued as COSV63932427; called by muse, mutect2, varscan2
- TGM4 | c.599C>T p.S200F | Missense Mutation (SNP) | VAF 123/136 reads (90%) | SIFT tolerated (0.69); PolyPhen benign (0.206); catalogued as COSV56096474; called by muse, mutect2, varscan2
- TGM7 | c.143G>A p.S48N | Missense Mutation (SNP) | VAF 122/139 reads (88%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV71773118; called by muse, mutect2, varscan2
- THAP12 | c.215C>T p.P72L | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as COSV52613056; called by muse, mutect2, varscan2
- THEMIS | c.769G>A p.D257N | Missense Mutation (SNP) | VAF 63/68 reads (93%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.642); catalogued as COSV64069772; called by muse, mutect2, varscan2
- TIGD4 | c.808C>T p.R270* | Nonsense Mutation (SNP) | VAF 42/147 reads (29%) | catalogued as rs761897713, COSV58550872; called by muse, mutect2, varscan2
- TLL2 | c.2002G>A p.E668K | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as COSV63575818; called by muse, mutect2, varscan2
- TLR10 | c.2059G>A p.E687K | Missense Mutation (SNP) | VAF 80/121 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58302288; called by muse, mutect2, varscan2
- TM2D2 | c.46C>T p.Q16* | Nonsense Mutation (SNP) | VAF 99/232 reads (43%) | catalogued as COSV65962429; called by muse, mutect2, varscan2
- TM9SF2 | c.1780C>T p.L594F | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.06); catalogued as COSV100899721; called by muse, mutect2
- TMC2 | c.1949C>T p.S650F | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV62658183; called by muse, mutect2, varscan2
- TMEM161A | c.441C>T p.S147= | Splice Region (SNP) | VAF 64/140 reads (46%) | catalogued as rs771234951, COSV50777193; called by muse, mutect2, varscan2
- TMEM41A | c.353G>A p.C118Y | Missense Mutation (SNP) | VAF 27/147 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.195); catalogued as COSV56188525; called by muse, mutect2, varscan2
- TMEM59L | c.863C>T p.T288I | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs1278123860, COSV53243507; called by muse, mutect2, varscan2
- TNC | c.5087G>A p.G1696E | Missense Mutation (SNP) | VAF 74/179 reads (41%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.991); catalogued as COSV60790238; called by muse, mutect2, varscan2
- TNMD | c.379A>G p.K127E | Missense Mutation (SNP) | VAF 24/28 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV65977781; called by muse, mutect2, varscan2
- TP53BP2 | c.131C>T p.P44L | Missense Mutation (SNP) | VAF 89/96 reads (93%) | SIFT deleterious (0); PolyPhen benign (0.36); catalogued as rs746194354, COSV100636679, COSV59071527; called by muse, mutect2, varscan2
- TPK1 | c.454C>T p.P152S | Missense Mutation (SNP) | VAF 67/135 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV63648057, COSV63648765; called by muse, mutect2, varscan2
- TRIM17 | c.806C>T p.P269L | Missense Mutation (SNP) | VAF 17/396 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.702); catalogued as COSV99488491; called by muse, mutect2
- TRIP10 | c.1426C>T p.L476F (on ENST00000313244 / NM_001288962.2; = p.L420F on NM_004240.4) | Missense Mutation (SNP) | VAF 83/179 reads (46%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.543); catalogued as COSV55588641; called by muse, mutect2, varscan2
- TRPM2 | c.3462-2A>G p.X1154_splice | Splice Site (SNP) | VAF 18/33 reads (55%) | catalogued as COSV100308947; called by muse, mutect2, varscan2
- TRPM3 | c.3293C>T p.A1098V (on ENST00000357533 / NM_001366142.2; = p.A953V on NM_020952.6) | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV62594602; called by muse, mutect2, varscan2
- TSBP1 | c.1622C>T p.S541L (on ENST00000617061; = p.S546L on NM_006781.5) | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.963); catalogued as rs746232383, COSV66660192; called by muse, mutect2, varscan2
- TSC2 | c.4800_4801del p.C1600Wfs*2 | Frame Shift Del (DEL) | VAF 8/63 reads (13%) | catalogued as rs1567533467; called by pindel, varscan2
- TTN | c.88672G>A p.E29558K (on ENST00000591111; = p.E22134K on NM_003319.4) | Missense Mutation (SNP) | VAF 18/18 reads (100%) | PolyPhen benign (0.229); catalogued as COSV60070648; called by muse, varscan2
- TTN | c.14755G>A p.G4919S (on ENST00000591111; = p.G3992S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/45 reads (76%) | PolyPhen possibly damaging (0.639); catalogued as COSV60340842; called by muse, mutect2, varscan2
- TTN | c.2350G>A p.G784R (on ENST00000591111; = p.G738R on NM_003319.4) | Missense Mutation (SNP) | VAF 19/50 reads (38%) | PolyPhen benign (0.011); catalogued as COSV60230919; called by muse, mutect2, varscan2
- TUB | c.139G>A p.G47S | Missense Mutation (SNP) | VAF 21/33 reads (64%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.994); catalogued as rs769088023, COSV59493537; called by muse, mutect2, varscan2
- TYROBP | c.65T>G p.L22R | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.653); catalogued as COSV52888560; called by muse, mutect2, varscan2
- UBD | c.35T>A p.V12D | Missense Mutation (SNP) | VAF 39/78 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV63542476, COSV63544498; called by muse, mutect2, varscan2
- UBE2J2 | c.215C>T p.P72L | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59571971; called by muse, mutect2, varscan2
- UBR5 | c.8099C>A p.S2700* | Nonsense Mutation (SNP) | VAF 14/67 reads (21%) | catalogued as COSV55283645, COSV99641163; called by muse, mutect2, varscan2
- UBR5 | c.8098T>A p.S2700T | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.763); catalogued as COSV99641166; called by muse, mutect2, varscan2
- UGT1A6 | c.530C>T p.S177F | Missense Mutation (SNP) | VAF 52/160 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.515); catalogued as COSV100530370; called by mutect2, varscan2
- UGT2B11 | c.1003-1G>A p.X335_splice | Splice Site (SNP) | VAF 6/28 reads (21%) | catalogued as rs866136620, COSV101485281, COSV71423791; called by muse, mutect2, varscan2
- UGT3A1 | c.896C>T p.A299V | Missense Mutation (SNP) | VAF 38/50 reads (76%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.597); catalogued as COSV99954890; called by muse, mutect2, varscan2
- UMODL1 | c.1381G>A p.G461R | Missense Mutation (SNP) | VAF 135/289 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61161485; called by muse, mutect2, varscan2
- USH1G | c.286A>T p.N96Y | Missense Mutation (SNP) | VAF 129/144 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58883695; called by muse, mutect2, varscan2
- USHBP1 | c.850C>T p.Q284* | Nonsense Mutation (SNP) | VAF 76/181 reads (42%) | catalogued as COSV53106072; called by muse, mutect2, varscan2
- USP28 | c.538C>T p.L180F | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50190815; called by mutect2, varscan2
- USP45 | c.2422C>T p.L808F | Missense Mutation (SNP) | VAF 45/53 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764688891, COSV59678262, COSV59682735; called by muse, mutect2, varscan2
- USP9X | c.85C>T p.Q29* | Nonsense Mutation (SNP) | VAF 4/26 reads (15%) | catalogued as COSV61075033; called by muse, mutect2, varscan2
- VARS2 | c.385-1G>A p.X129_splice | Splice Site (SNP) | VAF 78/166 reads (47%) | catalogued as COSV52561105; called by muse, mutect2, varscan2
- VN1R2 | c.907C>T p.L303F | Missense Mutation (SNP) | VAF 72/164 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.414); catalogued as COSV59039645; called by muse, mutect2, varscan2
- VPS13B | c.644G>A p.R215Q | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1268293833, COSV62020477; called by muse, mutect2, varscan2
- WASF1 | c.755T>A p.L252H | Missense Mutation (SNP) | VAF 47/56 reads (84%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.993); catalogued as COSV100846900; called by muse, mutect2, varscan2
- WASF1 | c.754C>T p.L252F | Missense Mutation (SNP) | VAF 48/56 reads (86%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.986); catalogued as COSV100846901; called by muse, mutect2, varscan2
- WDR33 | c.3013C>T p.P1005S | Missense Mutation (SNP) | VAF 18/350 reads (5%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.003); catalogued as COSV59255436; called by muse, mutect2
- WDR49 | c.1627G>A p.E543K (on ENST00000308378 / NM_001366158.1; = p.E884K on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs867011458, COSV57706145; called by muse, mutect2, varscan2
- WDR64 | c.1922C>T p.P641L | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT tolerated (0.21); PolyPhen benign (0.055); catalogued as COSV63800412; called by muse, mutect2, varscan2
- WFDC10B | c.92G>A p.R31K | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT tolerated (0.98); PolyPhen benign (0.006); catalogued as COSV57914901; called by muse, mutect2, varscan2
- WIPI1 | c.838G>A p.G280R | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs756847095, COSV50931721; called by muse, mutect2, varscan2
- WNT7A | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 27/30 reads (90%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.777); catalogued as COSV53202128; called by muse, mutect2, varscan2
- XPR1 | c.178C>T p.Q60* | Nonsense Mutation (SNP) | VAF 67/120 reads (56%) | catalogued as COSV62560496; called by muse, mutect2, varscan2
- YIPF7 | c.637C>T p.P213S | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60658191; called by muse, mutect2, varscan2
- YLPM1 | c.2455C>T p.Q819* | Nonsense Mutation (SNP) | VAF 30/35 reads (86%) | catalogued as COSV53120253; called by muse, mutect2, varscan2
- ZAN | c.3479G>A p.G1160E | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1441800391, COSV61816193; called by muse, mutect2, varscan2
- ZBBX | c.1285C>T p.H429Y | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as COSV56801153; called by muse, mutect2, varscan2
- ZBTB22 | c.1196C>T p.S399L | Missense Mutation (SNP) | VAF 143/419 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs770352144, COSV56472593, COSV99802159; called by muse, mutect2, varscan2
- ZBTB7B | c.295C>A p.L99I (on ENST00000292176; = p.L133I on NM_001252406.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV52694425, COSV52694778; called by muse, mutect2, varscan2
- ZBTB9 | c.211C>T p.P71S | Missense Mutation (SNP) | VAF 119/558 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1352641392, COSV101221765; called by muse, mutect2, varscan2
- ZBTB9 | c.212C>T p.P71L | Missense Mutation (SNP) | VAF 120/565 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101221766, COSV67702162; called by muse, mutect2, varscan2
- ZFC3H1 | c.5198G>A p.G1733E | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV66435782; called by muse, mutect2, varscan2
- ZFHX3 | c.6506C>T p.S2169F | Missense Mutation (SNP) | VAF 59/107 reads (55%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV51735199; called by muse, mutect2, varscan2
- ZFHX4 | c.1020del p.K340Nfs*15 | Frame Shift Del (DEL) | VAF 14/105 reads (13%) | catalogued as rs774274741; called by mutect2, pindel, varscan2
- ZFYVE9 | c.3247C>T p.R1083* | Nonsense Mutation (SNP) | VAF 31/63 reads (49%) | catalogued as COSV55100075; called by muse, mutect2, varscan2
- ZGPAT | c.638C>T p.P213L | Missense Mutation (SNP) | VAF 38/83 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.164); catalogued as rs903150759, COSV58874990; called by muse, mutect2, varscan2
- ZIM3 | c.235C>T p.R79C | Missense Mutation (SNP) | VAF 45/115 reads (39%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.446); catalogued as rs759820461, COSV54142834; called by muse, mutect2
- ZNF106 | c.1444del p.S482Pfs*33 | Frame Shift Del (DEL) | VAF 45/137 reads (33%) | catalogued as rs1198467282, COSV55516091; called by mutect2, varscan2
- ZNF134 | c.1111C>T p.P371S | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.949); catalogued as rs376143953; called by muse, mutect2, varscan2
- ZNF157 | c.641G>A p.G214E | Missense Mutation (SNP) | VAF 25/31 reads (81%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as COSV65659771; called by muse, mutect2, varscan2
- ZNF160 | c.706C>T p.H236Y | Missense Mutation (SNP) | VAF 46/118 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV62000014, COSV62000935; called by muse, mutect2, varscan2
- ZNF267 | c.1672C>T p.P558S | Missense Mutation (SNP) | VAF 29/43 reads (67%) | SIFT tolerated (0.99); PolyPhen benign (0.013); catalogued as COSV56256255; called by muse, mutect2, varscan2
- ZNF276 | c.487G>A p.G163S (on ENST00000443381 / NM_001113525.2; = p.G88S on NM_152287.4) | Missense Mutation (SNP) | VAF 72/133 reads (54%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.68); catalogued as rs748405201, COSV57065622; called by muse, mutect2, varscan2
- ZNF415 | c.602C>T p.S201L | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.327); catalogued as COSV54699345; called by muse, mutect2, varscan2
463 further variants in this file (33 protein-altering or splice-affecting, 403 silent, 27 other) are not listed here.
